Somatic mutation profile of tumor specimen C3N-01172-01 (aliquot CPT0095230009) from CPTAC case C3N-01172, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G2; Age at diagnosis: 57.1 years (20,873 days).
Specimen C3N-01172-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a42e4e6e-5eda-444c-ac85-65396638b779.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01172-31 (Blood Derived Normal), aliquot CPT0095270002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/088616c2-8715-4b78-a5df-6548396819a4

The open-access MAF lists 715 somatic variants for this specimen: 485 protein-altering or splice-affecting, 129 silent, 101 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 319, Silent 129, Frame Shift Del 105, Intron 59, Nonsense Mutation 23, Frame Shift Ins 18, 3'UTR 13, 5'UTR 12, RNA 9, In Frame Del 8, Splice Site 7, 5'Flank 6.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC6 | c.280del p.I94Sfs*22 | Frame Shift Del (DEL) | VAF 46/370 reads (12%) | catalogued as rs1555522997; ClinVar: pathogenic; called by mutect2, pindel
- BCKDHB | c.714dup p.E239* | Frame Shift Ins (INS) | VAF 67/180 reads (37%) | catalogued as rs1167005638; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 95/232 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NPC1 | c.1819C>T p.R607* | Nonsense Mutation (SNP) | VAF 120/308 reads (39%) | catalogued as rs377130051, CM020042; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.113G>A p.R38H | Missense Mutation (SNP) | VAF 50/119 reads (42%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs772110575, COSV55879949, COSV56003293; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.388C>T p.R130* | Nonsense Mutation (SNP) | VAF 130/347 reads (37%) | hotspot (GDC flag); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 183/451 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA3 | c.1087A>G p.M363V | Missense Mutation (SNP) | VAF 117/278 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.472); catalogued as COSV100068374, COSV57053882; called by muse, mutect2, varscan2
- ABTB2 | c.3038C>T p.A1013V | Missense Mutation (SNP) | VAF 74/177 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.043); catalogued as rs746443994; called by muse, mutect2, varscan2
- ABTB2 | c.2110G>A p.E704K | Missense Mutation (SNP) | VAF 110/256 reads (43%) | SIFT tolerated (0.65); PolyPhen benign (0.037); catalogued as rs745440994, COSV54387699; called by muse, mutect2, varscan2
- ACACB | c.1495C>T p.R499C | Missense Mutation (SNP) | VAF 96/295 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs978164597, COSV100622284; called by muse, mutect2, varscan2
- ACHE | c.587G>A p.R196Q | Missense Mutation (SNP) | VAF 26/278 reads (9%) | SIFT tolerated (0.76); PolyPhen benign (0.024); catalogued as rs763331269; called by muse, mutect2
- ADAM8 | c.1281del p.E428Rfs*32 | Frame Shift Del (DEL) | VAF 19/49 reads (39%) | catalogued as rs753471255, COSV69864363; called by mutect2, pindel, varscan2
- ADCY1 | c.1034G>A p.R345H | Missense Mutation (SNP) | VAF 49/108 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.04); catalogued as COSV52036922; called by muse, mutect2, varscan2
- ADGRF4 | c.245dup p.W83Vfs*6 | Frame Shift Ins (INS) | VAF 47/140 reads (34%) | catalogued as rs764604854; called by mutect2, varscan2
- ADGRL4 | c.55A>G p.T19A | Missense Mutation (SNP) | VAF 63/142 reads (44%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as rs749415468; called by muse, mutect2, varscan2
- ADGRV1 | c.3140_3141insG p.R1048Kfs*9 | Frame Shift Ins (INS) | VAF 62/193 reads (32%) | catalogued as COSV67983786; called by mutect2, varscan2*
- AKR1C3 | c.773G>A p.R258H | Missense Mutation (SNP) | VAF 25/131 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.783); catalogued as rs1305543060; called by muse, mutect2, varscan2
- ANKRD12 | c.2804del p.N935Ifs*24 | Frame Shift Del (DEL) | VAF 48/96 reads (50%) | catalogued as rs868780344; called by mutect2, varscan2
- ANTKMT | c.370G>A p.A124T | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.053); catalogued as rs754064432; called by muse, mutect2, varscan2
- AP000812.4 | c.650G>A p.R217Q | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.06); catalogued as rs372524977; called by muse, mutect2, varscan2
- AP2A2 | c.1609C>T p.R537C | Missense Mutation (SNP) | VAF 8/196 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59957728; called by muse, mutect2
- ARHGAP10 | c.805G>A p.E269K | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as rs915927270, COSV60599071; called by muse, mutect2, varscan2
- ARMCX3 | c.592C>T p.R198C | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.964); catalogued as rs372051555, COSV57871198; called by muse, mutect2, varscan2
- ASB18 | c.677C>T p.A226V | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.916); catalogued as rs1241223578, COSV100430929; called by muse, mutect2, varscan2
- BAALC | c.376del p.Q126Rfs*8 (on ENST00000297574 / NM_001364874.1; = p.Q91Rfs*8 on NM_024812.3) | Frame Shift Del (DEL) | VAF 62/186 reads (33%) | catalogued as COSV99883875; called by mutect2, pindel, varscan2
- BEND7 | c.102_104del p.E35del | In Frame Del (DEL) | VAF 22/88 reads (25%) | catalogued as rs772426797; called by pindel, varscan2
- BMPR1A | c.760C>T p.R254C | Missense Mutation (SNP) | VAF 100/291 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs587782578, COSV64404965; ClinVar: uncertain significance / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- BRD8 | c.2250-3del | Splice Region (DEL) | VAF 18/43 reads (42%) | catalogued as rs749043197; called by mutect2, varscan2
- C16orf86 | c.932del p.P311Rfs*31 | Frame Shift Del (DEL) | VAF 96/270 reads (36%) | catalogued as rs1388939326; called by mutect2, pindel, varscan2
- C1RL | c.547G>A p.A183T | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs776456048; called by muse, mutect2, varscan2
- C7 | c.1328G>T p.W443L | Missense Mutation (SNP) | VAF 45/123 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as COSV100496482; called by muse, mutect2, varscan2
- CABIN1 | c.1976G>A p.R659Q | Missense Mutation (SNP) | VAF 116/343 reads (34%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs200579275, COSV99572893; called by muse, mutect2, varscan2
- CACNB3 | c.472+13del | Splice Region (DEL) | VAF 35/117 reads (30%) | catalogued as rs778256532; called by pindel, varscan2
- CARMIL1 | c.2789G>A p.R930Q | Missense Mutation (SNP) | VAF 43/105 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61517006; called by muse, mutect2, varscan2
- CARS1 | c.1679C>T p.A560V | Missense Mutation (SNP) | VAF 83/205 reads (40%) | SIFT tolerated (0.52); PolyPhen benign (0.02); catalogued as rs1270565420; called by muse, mutect2, varscan2
- CCDC9B | c.294del p.M99Wfs*3 | Frame Shift Del (DEL) | VAF 33/176 reads (19%) | catalogued as rs765438623; called by mutect2, varscan2
- CD177 | c.1258del p.V420Wfs*30 | Frame Shift Del (DEL) | VAF 24/68 reads (35%) | catalogued as COSV65121341; called by mutect2, pindel, varscan2
- CDC7 | c.92del p.N31Tfs*51 | Frame Shift Del (DEL) | VAF 26/149 reads (17%) | catalogued as rs762194001; called by mutect2, varscan2
- CDK20 | c.955del p.H319Tfs*16 (on ENST00000325303 / NM_001039803.3; = p.H298Tfs*16 on NM_012119.4) | Frame Shift Del (DEL) | VAF 29/70 reads (41%) | catalogued as rs749463697; called by mutect2, pindel, varscan2
- CELSR3 | c.3856C>T p.R1286C | Missense Mutation (SNP) | VAF 77/206 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs1418729394, COSV99372152; called by muse, mutect2, varscan2
- CFAP46 | c.4522G>A p.A1508T | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as rs779226172; called by muse, mutect2, varscan2
- CHAMP1 | c.2306G>A p.R769H | Missense Mutation (SNP) | VAF 46/117 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.019); catalogued as COSV63521905; called by muse, mutect2, varscan2
- CHD3 | c.1618dup p.R540Pfs*47 | Frame Shift Ins (INS) | VAF 82/223 reads (37%) | catalogued as rs747299117; called by mutect2, varscan2
- CLCC1 | c.1327C>T p.R443W (on ENST00000356970 / NM_001377464.1; = p.R393W on NM_015127.5) | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs778267768, COSV100206411; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CLCN6 | c.2509G>A p.V837M | Missense Mutation (SNP) | VAF 80/221 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs968167686, COSV56741872; called by muse, mutect2, varscan2
- CLEC17A | c.144G>T p.E48D | Missense Mutation (SNP) | VAF 44/137 reads (32%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); catalogued as rs780733761, COSV60429301; called by muse, mutect2, varscan2
- CNGB1 | c.503G>T p.R168I | Missense Mutation (SNP) | VAF 96/237 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.276); catalogued as COSV51905006; called by muse, mutect2, varscan2
- CNR2 | c.919C>T p.R307C | Missense Mutation (SNP) | VAF 80/152 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.066); catalogued as rs773572627, COSV65694683; called by muse, mutect2, varscan2
- COG2 | c.906del p.G303Afs*11 | Frame Shift Del (DEL) | VAF 37/96 reads (39%) | catalogued as rs779434837; called by mutect2, pindel, varscan2
- COL19A1 | c.1354C>T p.H452Y | Missense Mutation (SNP) | VAF 40/122 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs768413357; called by muse, varscan2
- CSMD3 | c.4420G>A p.G1474S (on ENST00000297405 / NM_001363185.1; = p.G1370S on NM_052900.3) | Missense Mutation (SNP) | VAF 94/282 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV52321900, COSV99830280; called by muse, mutect2, varscan2
- CUX1 | c.2389del p.Q797Rfs*11 | Frame Shift Del (DEL) | VAF 77/214 reads (36%) | catalogued as COSV99472907; called by mutect2, pindel, varscan2
- DAGLB | c.412G>A p.V138M | Missense Mutation (SNP) | VAF 44/97 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.419); catalogued as rs139914849; called by muse, mutect2, varscan2
- DEPDC5 | c.2054G>A p.R685H (on ENST00000400246; = p.R754H on NM_014662.5) | Missense Mutation (SNP) | VAF 107/250 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.564); catalogued as rs542384516; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DHX30 | c.3460C>T p.R1154C (on ENST00000445061 / NM_138615.3; = p.R1115C on NM_014966.3) | Missense Mutation (SNP) | VAF 77/211 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs771382815; called by muse, mutect2, varscan2
- DISC1 | c.41G>C p.G14A | Missense Mutation (SNP) | VAF 57/104 reads (55%) | SIFT tolerated (1); PolyPhen benign (0.083); catalogued as rs1016488464, CM080198; called by muse, mutect2, varscan2
- DMXL1 | c.2467-1G>C p.X823_splice | Splice Site (SNP) | VAF 59/134 reads (44%) | catalogued as COSV100223737; called by muse, mutect2, varscan2
- DNAH1 | c.1534G>A p.A512T | Missense Mutation (SNP) | VAF 122/289 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.166); catalogued as rs761858704; called by muse, mutect2, varscan2
- DRC3 | c.410C>T p.S137L | Missense Mutation (SNP) | VAF 71/153 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs1302306792; called by muse, mutect2, varscan2
- DUS4L-BCAP29 | c.1060del p.W354Gfs*2 | Frame Shift Del (DEL) | VAF 26/84 reads (31%) | catalogued as rs746928635; called by mutect2, varscan2
- EPN1 | c.1577C>T p.A526V (on ENST00000270460 / NM_001321263.1; = p.A500V on NM_013333.3) | Missense Mutation (SNP) | VAF 91/229 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.151); catalogued as rs534374149, COSV50038250; called by muse, mutect2, varscan2
- F11 | c.646G>A p.D216N | Missense Mutation (SNP) | VAF 12/244 reads (5%) | SIFT tolerated (0.53); PolyPhen benign (0.198); catalogued as CM097442; called by muse, mutect2
- FAM20C | c.838G>A p.G280R | Missense Mutation (SNP) | VAF 43/146 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs779708323, CM091203, COSV100570698, COSV58234675; called by muse, mutect2, varscan2
- FAN1 | c.2228G>A p.R743H | Missense Mutation (SNP) | VAF 66/162 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as rs1315381732, COSV100755791; called by muse, mutect2, varscan2
- FAT2 | c.10765G>A p.A3589T | Missense Mutation (SNP) | VAF 78/170 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as rs755118559; called by muse, mutect2, varscan2
- FBN2 | c.3710G>A p.R1237H | Missense Mutation (SNP) | VAF 146/355 reads (41%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.947); catalogued as rs142185964, COSV52513207; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- FBXL20 | c.617C>T p.T206M | Missense Mutation (SNP) | VAF 55/132 reads (42%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.714); catalogued as rs532621624, COSV52896822; called by muse, mutect2, varscan2
- FHOD3 | c.710C>T p.T237M | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.793); catalogued as rs765568380, COSV57165633; called by muse, mutect2, varscan2
- FIZ1 | c.916G>A p.G306R | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs762214365, COSV99684745; called by muse, mutect2, varscan2
- FKBP10 | c.587G>A p.S196N | Missense Mutation (SNP) | VAF 18/426 reads (4%) | SIFT tolerated (0.65); PolyPhen benign (0.062); catalogued as rs782660556; ClinVar: uncertain significance; called by muse, mutect2
- FLOT2 | c.859C>T p.R287C | Missense Mutation (SNP) | VAF 90/217 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as rs756020730, COSV67528913; called by muse, mutect2, varscan2
- FOXD3 | c.281del p.G94Afs*46 | Frame Shift Del (DEL) | VAF 11/27 reads (41%) | catalogued as rs1453047553; called by mutect2, pindel, varscan2
- FOXI1 | c.177del p.N60Tfs*11 | Frame Shift Del (DEL) | VAF 34/77 reads (44%) | catalogued as COSV60388686; called by mutect2, pindel, varscan2
- FSCN2 | c.1071_1073del p.K357del | In Frame Del (DEL) | VAF 50/174 reads (29%) | catalogued as rs760309853; called by pindel, varscan2
- FTCD | c.1021C>T p.R341C | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT tolerated (0.05); PolyPhen benign (0.024); catalogued as rs1208719468, COSV52426624; called by muse, varscan2
- FUT7 | c.556C>T p.R186C | Missense Mutation (SNP) | VAF 51/109 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765235155; called by muse, mutect2, varscan2
- GATB | c.1048G>A p.D350N | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.951); catalogued as rs767698940; called by muse, mutect2, varscan2
- GFRAL | c.300del p.K100Nfs*9 | Frame Shift Del (DEL) | VAF 15/57 reads (26%) | catalogued as rs755972268; called by mutect2, pindel, varscan2
- GMNN | c.199del p.V67Lfs*23 | Frame Shift Del (DEL) | VAF 31/88 reads (35%) | catalogued as COSV57776934; called by mutect2, pindel, varscan2
- GNB3 | c.88C>A p.L30M | Missense Mutation (SNP) | VAF 34/116 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.118); catalogued as COSV99301266; called by muse, mutect2, varscan2
- GP5 | c.113del p.G38Afs*9 | Frame Shift Del (DEL) | VAF 61/188 reads (32%) | catalogued as rs750629635; called by mutect2, pindel, varscan2
- GPAM | c.251C>T p.P84L | Missense Mutation (SNP) | VAF 66/172 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1360350889, COSV62082304; called by muse, mutect2, varscan2
- GRIP1 | c.2752G>A p.V918M (on ENST00000359742 / NM_001379345.1; = p.V866M on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 126/316 reads (40%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.082); catalogued as rs1196200653; called by muse, mutect2, varscan2
- GRM8 | c.2158del p.H720Tfs*12 | Frame Shift Del (DEL) | VAF 38/116 reads (33%) | catalogued as COSV58842099; called by pindel, varscan2
- GSR | c.1436T>C p.M479T | Missense Mutation (SNP) | VAF 122/302 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.823); catalogued as rs1384286643, COSV55319782; called by muse, varscan2
- GUCA2A | c.292G>A p.A98T | Missense Mutation (SNP) | VAF 85/197 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs764772255, COSV63691203; called by muse, mutect2, varscan2
- GUF1 | c.1934del p.K645Sfs*2 | Frame Shift Del (DEL) | VAF 14/124 reads (11%) | catalogued as COSV54945907; called by mutect2, varscan2
- HIC2 | c.1714C>T p.R572C | Missense Mutation (SNP) | VAF 76/184 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV101335541, COSV68042147; called by muse, mutect2, varscan2
- HLA-G | c.627del p.K210Rfs*4 | Frame Shift Del (DEL) | VAF 39/104 reads (38%) | catalogued as rs752829354, COSV64406835; called by mutect2, pindel, varscan2
- HMX1 | c.448G>A p.A150T | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.127); catalogued as rs376695621; called by muse, mutect2, varscan2
- HNRNPD | c.193G>A p.G65R | Missense Mutation (SNP) | VAF 93/166 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.299); catalogued as rs758248301; called by muse, mutect2, varscan2
- HOXD11 | c.200G>A p.G67D | Missense Mutation (SNP) | VAF 75/186 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs1385849563; called by muse, mutect2, varscan2
- HOXD8 | c.329del p.P110Lfs*67 | Frame Shift Del (DEL) | VAF 14/52 reads (27%) | catalogued as rs770632206; called by mutect2, pindel, varscan2
- HRH3 | c.952C>T p.R318C | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs201799413, COSV100420420; called by muse, mutect2, varscan2
- HSPA12B | c.844C>T p.R282C | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.911); catalogued as rs772736874; called by muse, mutect2
- HYDIN | c.11431C>T p.R3811C | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs111706881, COSV66637901; called by muse, mutect2, varscan2
- INPPL1 | c.3466del p.R1156Gfs*46 | Frame Shift Del (DEL) | VAF 61/92 reads (66%) | catalogued as rs760925109; called by mutect2, pindel, varscan2
- INTS8 | c.1318G>A p.A440T | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.295); catalogued as COSV58250625; called by muse, mutect2, varscan2
- ITK | c.937T>C p.F313L | Missense Mutation (SNP) | VAF 124/311 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV68435490; called by muse, mutect2, varscan2
- JAKMIP2 | c.787C>T p.R263* | Nonsense Mutation (SNP) | VAF 116/277 reads (42%) | catalogued as COSV54613248; called by muse, mutect2, varscan2
- KALRN | c.4480C>T p.R1494W | Missense Mutation (SNP) | VAF 58/145 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53752833; called by muse, mutect2, varscan2
- KCNE4 | c.223C>T p.R75C | Missense Mutation (SNP) | VAF 77/182 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.599); catalogued as rs750286653, COSV56054846; called by muse, mutect2, varscan2
- KCNK13 | c.589G>A p.V197I | Missense Mutation (SNP) | VAF 88/241 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs536825700, COSV56411462; called by muse, mutect2, varscan2
- KLF3 | c.677del p.P226Rfs*52 | Frame Shift Del (DEL) | VAF 36/80 reads (45%) | catalogued as COSV54711577; called by mutect2, varscan2
- KLHL36 | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT tolerated (0.63); PolyPhen benign (0.024); catalogued as rs1380754254; called by muse, mutect2, varscan2
- KMT2B | c.5590C>T p.R1864* | Nonsense Mutation (SNP) | VAF 108/219 reads (49%) | catalogued as COSV55856587; called by muse, mutect2, varscan2
- KRT5 | c.506G>A p.R169H | Missense Mutation (SNP) | VAF 112/237 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as rs60720877, CM062803; called by muse, mutect2, varscan2
- KRTAP10-4 | c.312del p.C105Afs*75 | Frame Shift Del (DEL) | VAF 47/466 reads (10%) | catalogued as COSV59979735; called by pindel, varscan2
- LILRA6 | c.1384G>T p.G462W | Missense Mutation (SNP) | VAF 43/121 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54432374; called by muse, mutect2, varscan2
- LMLN2 | c.1433C>T p.P478L | Missense Mutation (SNP) | VAF 70/195 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.099); catalogued as rs1238010160; called by muse, mutect2, varscan2
- LONP1 | c.298A>G p.S100G | Missense Mutation (SNP) | VAF 98/253 reads (39%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs754822223; called by muse, mutect2, varscan2
- LPA | c.4289C>T p.A1430V | Missense Mutation (SNP) | VAF 79/211 reads (37%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.702); catalogued as rs370793685, COSV60298183; called by muse, mutect2, varscan2
- LRCH4 | c.643C>T p.R215C | Missense Mutation (SNP) | VAF 38/117 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs753461028; called by muse, mutect2, varscan2
- LRP1B | c.13319G>A p.S4440N | Missense Mutation (SNP) | VAF 54/130 reads (42%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs1269947097; called by muse, mutect2, varscan2
- LRRC75B | c.518G>A p.R173H | Missense Mutation (SNP) | VAF 78/198 reads (39%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs376304947; called by muse, mutect2, varscan2
- MADCAM1 | c.902C>T p.T301M | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.23); PolyPhen benign (0.277); catalogued as rs200220692; called by muse, varscan2
- MADD | c.797G>A p.R266Q | Missense Mutation (SNP) | VAF 84/169 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs768055248; called by muse, mutect2, varscan2
- MAGEB6B | c.155G>A p.R52H | Missense Mutation (SNP) | VAF 142/302 reads (47%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs764042835; called by muse, mutect2, varscan2
- MAGEL2 | c.1303C>T p.P435S | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as rs1296167802; called by muse, mutect2, varscan2
- MAK | c.1246G>A p.G416R | Missense Mutation (SNP) | VAF 78/184 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.873); catalogued as rs773588644, COSV100504561; called by muse, mutect2, varscan2
- MAN1A1 | c.344C>T p.A115V | Missense Mutation (SNP) | VAF 48/92 reads (52%) | SIFT tolerated (0.36); PolyPhen benign (0.055); catalogued as rs917392046; called by muse, mutect2, varscan2
- MAP1S | c.1039C>T p.R347W | Missense Mutation (SNP) | VAF 92/278 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV60723346; called by muse, mutect2, varscan2
- MAP7D2 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 22/128 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs774230355; called by muse, mutect2, varscan2
- MAP9 | c.1901C>T p.P634L | Missense Mutation (SNP) | VAF 60/141 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs749611120, COSV60906381; called by muse, mutect2, varscan2
- MAPK8IP3 | c.2077G>A p.V693M | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs534419557; called by muse, mutect2, varscan2
- MATN2 | c.904G>A p.V302I | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT tolerated (0.36); PolyPhen benign (0.09); catalogued as rs760575035, COSV99646212; called by muse, mutect2, varscan2
- MCF2L2 | c.520G>A p.G174S | Missense Mutation (SNP) | VAF 52/119 reads (44%) | SIFT tolerated (0.39); PolyPhen benign (0.125); catalogued as rs376645473, COSV100191426; called by muse, mutect2, varscan2
- MGAT3 | c.384del p.P130Rfs*24 | Frame Shift Del (DEL) | VAF 12/36 reads (33%) | catalogued as rs768261467, COSV57864436; called by mutect2, pindel, varscan2
- MIB2 | c.1760C>T p.A587V | Missense Mutation (SNP) | VAF 70/174 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs536201760; called by muse, mutect2, varscan2
- MIDEAS | c.939del p.N314Tfs*4 | Frame Shift Del (DEL) | VAF 14/39 reads (36%) | catalogued as rs762448666; called by mutect2, pindel, varscan2
- MISP | c.1037G>A p.R346H | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as rs771407225, COSV53118816; called by muse, mutect2, varscan2
- MROH2B | c.4114del p.I1372Sfs*5 | Frame Shift Del (DEL) | VAF 54/128 reads (42%) | catalogued as rs756600463; called by mutect2, varscan2
- MROH6 | c.953G>A p.R318H | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); catalogued as rs774820460; called by muse, mutect2, varscan2
- MYBBP1A | c.2888C>T p.P963L | Missense Mutation (SNP) | VAF 38/85 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs368155160; called by muse, mutect2
- MYH3 | c.1006G>A p.A336T | Missense Mutation (SNP) | VAF 144/360 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1336684067, COSV56862838; called by muse, mutect2, varscan2
- NCOR2 | c.3904dup p.H1302Pfs*2 | Frame Shift Ins (INS) | VAF 26/81 reads (32%) | catalogued as rs768164546; called by mutect2, varscan2
- NDUFA10 | c.604del p.H202Tfs*3 | Frame Shift Del (DEL) | VAF 128/306 reads (42%) | catalogued as rs746019378; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- NEUROD1 | c.431G>A p.R144H | Missense Mutation (SNP) | VAF 100/251 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54548631, COSV54549328; called by muse, mutect2, varscan2
- NKX6-1 | c.1060G>A p.G354S | Missense Mutation (SNP) | VAF 58/123 reads (47%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.009); catalogued as COSV55685369; called by muse, mutect2, varscan2
- NOC3L | c.719G>A p.R240H | Missense Mutation (SNP) | VAF 59/123 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs989221465, COSV64930403; called by muse, mutect2, varscan2
- NOL4 | c.226G>A p.G76S | Missense Mutation (SNP) | VAF 62/161 reads (39%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV99308624; called by muse, mutect2, varscan2
- NRGN | c.83C>T p.A28V | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.825); catalogued as COSV99423451, COSV99423565; called by muse, mutect2, varscan2
- NSD1 | c.2402C>T p.A801V | Missense Mutation (SNP) | VAF 23/164 reads (14%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1464918468; called by muse, mutect2, varscan2
- NT5M | c.622del p.R208Afs*34 | Frame Shift Del (DEL) | VAF 96/226 reads (42%) | catalogued as rs754390000; called by mutect2, varscan2
- NUTM2A | c.872C>T p.P291L | Missense Mutation (SNP) | VAF 44/215 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.934); catalogued as rs1224551905; called by muse, mutect2, varscan2
- NYAP1 | c.417del p.S140Afs*63 | Frame Shift Del (DEL) | VAF 17/45 reads (38%) | catalogued as rs1173074678; called by mutect2, pindel
- OBSCN | c.10589C>T p.T3530M | Missense Mutation (SNP) | VAF 158/335 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.279); catalogued as rs763051262, COSV52765057; called by muse, mutect2, varscan2
- OCRL | c.1710G>T p.R570S | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.075); catalogued as COSV63982200; called by muse, mutect2, varscan2
- OR10Z1 | c.265del p.D89Tfs*48 | Frame Shift Del (DEL) | VAF 52/154 reads (34%) | catalogued as rs752054889; called by mutect2, pindel, varscan2
- PAMR1 | c.302del p.G101Vfs*8 | Frame Shift Del (DEL) | VAF 53/192 reads (28%) | catalogued as rs751755759; called by mutect2, pindel, varscan2
- PARD6G | c.940del p.Q314Rfs*78 | Frame Shift Del (DEL) | VAF 20/58 reads (34%) | catalogued as rs755217812; called by mutect2, pindel
- PAWR | c.125del p.P42Rfs*48 | Frame Shift Del (DEL) | VAF 26/64 reads (41%) | catalogued as rs1555180541; called by mutect2, varscan2
- PCBP4 | c.452C>T p.T151M | Missense Mutation (SNP) | VAF 38/72 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs142190169; called by muse, mutect2, varscan2
- PCDH10 | c.679del p.Q227Sfs*43 | Frame Shift Del (DEL) | VAF 17/46 reads (37%) | catalogued as COSV52090150; called by mutect2, pindel, varscan2
- PCDH9 | c.2500G>A p.V834I | Missense Mutation (SNP) | VAF 94/221 reads (43%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.709); catalogued as rs375314712, COSV100122556, COSV60525121; called by muse, mutect2, varscan2
- PCDHA5 | c.1442C>T p.A481V | Missense Mutation (SNP) | VAF 21/511 reads (4%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.226); catalogued as rs1554129201, COSV100972227; called by muse, mutect2
- PCLO | c.10258C>T p.R3420* | Nonsense Mutation (SNP) | VAF 85/226 reads (38%) | catalogued as COSV61619136; called by muse, mutect2, varscan2
- PDZD2 | c.7947G>A p.T2649= | Splice Region (SNP) | VAF 62/138 reads (45%) | catalogued as rs753725978; called by muse, mutect2, varscan2
- PLA2G4E | c.1611G>T p.E537D | Missense Mutation (SNP) | VAF 58/121 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101268509; called by muse, mutect2, varscan2
- PLA2G7 | c.382A>G p.M128V | Missense Mutation (SNP) | VAF 109/250 reads (44%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as rs928438839; called by muse, mutect2, varscan2
- PLCG1 | c.2489G>A p.R830Q | Missense Mutation (SNP) | VAF 70/173 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.716); catalogued as rs748571525; called by muse, mutect2, varscan2
- PLEKHG4B | c.2330del p.P777Rfs*30 (on ENST00000283426; = p.P1133Rfs*30 on NM_052909.5) | Frame Shift Del (DEL) | VAF 62/200 reads (31%) | catalogued as rs746346365, COSV52056100; called by mutect2, pindel, varscan2
- PLXNA2 | c.3077G>A p.R1026Q | Missense Mutation (SNP) | VAF 44/112 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.851); catalogued as rs760505532, COSV100885565; called by muse, mutect2, varscan2
- PLXNB3 | c.4963del p.V1655Cfs*7 | Frame Shift Del (DEL) | VAF 10/28 reads (36%) | catalogued as rs782076287; called by mutect2, varscan2
- POLA2 | c.1585G>A p.A529T | Missense Mutation (SNP) | VAF 61/137 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.111); catalogued as rs546255396, COSV55482842, COSV55482976; called by muse, mutect2, varscan2
- POTEH | c.1167-2A>G p.X389_splice | Splice Site (SNP) | VAF 8/22 reads (36%) | catalogued as rs762716462, COSV58879780; called by mutect2, varscan2
- PPP1R3A | c.2368C>T p.R790* | Nonsense Mutation (SNP) | VAF 60/134 reads (45%) | catalogued as rs1471160727, COSV52878990; called by muse, mutect2, varscan2
- PSG7 | c.680G>A p.R227H | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.019); catalogued as rs200257675, COSV68444203; called by muse, mutect2, varscan2
- PTEN | c.955_958del p.T319* | Frame Shift Del (DEL) | VAF 64/168 reads (38%) | catalogued as rs146650273; called by pindel, varscan2
- PTPRJ | c.620C>T p.P207L | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs775555539; called by muse, mutect2, varscan2
- PWWP2B | c.590C>T p.A197V | Missense Mutation (SNP) | VAF 45/89 reads (51%) | SIFT tolerated (0.23); PolyPhen benign (0.019); catalogued as rs750701942, COSV100535987; called by muse, mutect2, varscan2
- PYGB | c.553C>T p.R185C | Missense Mutation (SNP) | VAF 44/105 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs201326100, COSV53818914; called by muse, mutect2, varscan2
- RAD21L1 | c.1109C>G p.S370C | Missense Mutation (SNP) | VAF 45/121 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.864); catalogued as COSV67880838; called by muse, mutect2, varscan2
- RADIL | c.32C>T p.P11L | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT tolerated (0.27); PolyPhen benign (0.041); catalogued as rs867769739; called by muse, mutect2, varscan2
- RBM6 | c.2502del p.K834Nfs*27 | Frame Shift Del (DEL) | VAF 53/128 reads (41%) | catalogued as COSV56484832; called by mutect2, varscan2
- RECQL | c.1360C>T p.R454C | Missense Mutation (SNP) | VAF 47/117 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376377526; called by muse, mutect2, varscan2
- RGPD4 | c.43G>A p.V15M | Missense Mutation (SNP) | VAF 92/265 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.447); catalogued as COSV100736277, COSV61748523; called by muse, mutect2, varscan2
- RNF44 | c.1036C>T p.R346W | Missense Mutation (SNP) | VAF 63/164 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1300897504, COSV51269542; called by muse, mutect2, varscan2
- RUBCN | c.1153C>T p.R385C | Missense Mutation (SNP) | VAF 62/138 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs762804959; called by muse, mutect2, varscan2
- RYR3 | c.14072T>C p.F4691S (on ENST00000389232; = p.F4692S on NM_001036.6) | Missense Mutation (SNP) | VAF 94/234 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66785625; called by muse, mutect2, varscan2
- SCT | c.184G>A p.A62T | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.001); catalogued as rs1341059256; called by muse, mutect2, varscan2
- SEPTIN12 | c.629G>T p.R210M | Missense Mutation (SNP) | VAF 45/111 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV51617914; called by muse, mutect2, varscan2
- SETD4 | c.152C>T p.A51V | Missense Mutation (SNP) | VAF 46/111 reads (41%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs771217411; called by muse, mutect2, varscan2
- SETMAR | c.2005A>G p.I669V | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.076); catalogued as rs1223913903; called by muse, varscan2
- SF1 | c.1268del p.P423Lfs*10 | Frame Shift Del (DEL) | VAF 12/44 reads (27%) | catalogued as COSV57116990; called by mutect2, pindel, varscan2
- SF3B3 | c.2108G>A p.R703Q | Missense Mutation (SNP) | VAF 59/133 reads (44%) | SIFT tolerated (0.28); PolyPhen benign (0.009); catalogued as rs767028940, COSV56787169; called by muse, mutect2, varscan2
- SHANK3 | c.2948G>A p.R983H | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.83); catalogued as rs1368172348; called by muse, mutect2, varscan2
- SHPRH | c.3866G>A p.R1289Q (on ENST00000275233 / NM_001042683.3; = p.R1293Q on NM_173082.3) | Missense Mutation (SNP) | VAF 105/248 reads (42%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.996); catalogued as COSV99262430, COSV99262786; called by muse, mutect2, varscan2
- SLC26A7 | c.559G>A p.A187T | Missense Mutation (SNP) | VAF 48/133 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52589004; called by muse, mutect2, varscan2
- SLC7A10 | c.471del p.T158Pfs*12 | Frame Shift Del (DEL) | VAF 42/104 reads (40%) | catalogued as rs753589038, COSV53507811; called by mutect2, varscan2
- SLC8A2 | c.380C>T p.T127M | Missense Mutation (SNP) | VAF 158/355 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs956606101, COSV99370410; called by muse, mutect2, varscan2
- SNPH | c.662C>T p.P221L | Missense Mutation (SNP) | VAF 41/87 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.231); catalogued as rs776133925; called by muse, mutect2, varscan2
- SNTG2 | c.853A>G p.K285E | Missense Mutation (SNP) | VAF 61/173 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs944679961; called by muse, mutect2, varscan2
- SORL1 | c.4741del p.M1581Cfs*34 | Frame Shift Del (DEL) | VAF 28/91 reads (31%) | catalogued as rs1278336874; called by mutect2, pindel, varscan2
- SOX12 | c.381del p.G128Vfs*171 | Frame Shift Del (DEL) | VAF 20/43 reads (47%) | catalogued as rs1345087091; called by mutect2, varscan2
- SSH1 | c.1376G>A p.R459H | Missense Mutation (SNP) | VAF 102/223 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.028); catalogued as rs781444832, COSV58454351; called by muse, mutect2, varscan2
- STPG4 | c.519C>T p.P173= | Splice Region (SNP) | VAF 54/156 reads (35%) | catalogued as rs1254542385; called by muse, varscan2
- STRN4 | c.1985G>A p.R662H | Missense Mutation (SNP) | VAF 55/121 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as rs560915215, COSV54416450; called by muse, mutect2, varscan2
- SYN1 | c.1568C>T p.A523V | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs1341949224; called by muse, mutect2, varscan2
- SYNCRIP | c.1652G>A p.R551H | Missense Mutation (SNP) | VAF 48/98 reads (49%) | SIFT tolerated (0.18); PolyPhen benign (0.289); catalogued as COSV62288992; called by muse, mutect2, varscan2
- TBL1X | c.1699G>A p.D567N | Missense Mutation (SNP) | VAF 10/150 reads (7%) | SIFT tolerated (0.74); PolyPhen benign (0.077); catalogued as rs966604933; called by muse, mutect2
- TBX4 | c.1112del p.P371Lfs*8 | Frame Shift Del (DEL) | VAF 63/176 reads (36%) | catalogued as rs754897911; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- TECTA | c.2566G>A p.A856T | Missense Mutation (SNP) | VAF 57/140 reads (41%) | SIFT tolerated (0.55); PolyPhen benign (0.207); catalogued as rs145413004; called by muse, mutect2, varscan2
- TFIP11 | c.496C>T p.R166W | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as rs765698955; called by muse, mutect2, varscan2
- THAP7 | c.91_93del p.K31del | In Frame Del (DEL) | VAF 27/77 reads (35%) | catalogued as rs761208494; called by pindel, varscan2
- TLE1 | c.1851del p.D617Efs*70 | Frame Shift Del (DEL) | VAF 43/116 reads (37%) | catalogued as COSV64721731; called by mutect2, pindel, varscan2
- TMED3 | c.574G>A p.V192M | Missense Mutation (SNP) | VAF 47/144 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs960905878, COSV55303129; called by muse, mutect2, varscan2
- TMEM89 | c.154C>A p.L52M | Missense Mutation (SNP) | VAF 83/210 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV56570218; called by muse, mutect2, varscan2
- TP73 | c.1829C>T p.A610V | Missense Mutation (SNP) | VAF 70/158 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.783); catalogued as rs141747493; called by muse, mutect2, varscan2
- TRARG1 | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 47/83 reads (57%) | SIFT tolerated (0.68); PolyPhen benign (0.158); catalogued as rs751171532, COSV61562502, COSV61563020; called by muse, mutect2, varscan2
- TRIM40 | c.349C>T p.R117* | Nonsense Mutation (SNP) | VAF 61/114 reads (54%) | catalogued as rs774283475; called by muse, mutect2, varscan2
- TRPM5 | c.2161C>T p.L721F | Missense Mutation (SNP) | VAF 73/179 reads (41%) | SIFT tolerated (0.32); PolyPhen benign (0.073); catalogued as rs200948110; called by muse, mutect2, varscan2
- TTC33 | c.289G>C p.E97Q | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV61802990; called by muse, varscan2
- TTC7B | c.503G>A p.R168Q | Missense Mutation (SNP) | VAF 59/172 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.026); catalogued as rs750270226; called by muse, mutect2, varscan2
- TTN | c.66445C>T p.R22149C (on ENST00000591111; = p.R14725C on NM_003319.4) | Missense Mutation (SNP) | VAF 39/68 reads (57%) | PolyPhen possibly damaging (0.87); catalogued as rs775743818; ClinVar: likely benign; called by muse, mutect2, varscan2
- TUB | c.92G>A p.R31Q (on ENST00000299506 / NM_177972.3; = p.R86Q on NM_003320.4) | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as rs765032093; called by muse, mutect2, varscan2
- TUBA4A | c.467G>A p.R156Q | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.101); catalogued as rs752457075, COSV99944645; called by muse, mutect2, varscan2
- USP24 | c.2798G>A p.R933H | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.976); catalogued as rs757372143, COSV99601053; called by muse, mutect2, varscan2
- UTF1 | c.749del p.P250Rfs*26 | Frame Shift Del (DEL) | VAF 6/25 reads (24%) | catalogued as rs898770563; called by mutect2, pindel, varscan2
- VPS35 | c.631C>T p.R211* | Nonsense Mutation (SNP) | VAF 95/236 reads (40%) | catalogued as COSV100140483; called by muse, mutect2, varscan2
- VSX2 | c.419T>C p.L140S | Missense Mutation (SNP) | VAF 144/345 reads (42%) | SIFT tolerated (0.8); PolyPhen benign (0.083); catalogued as rs899470082; called by muse, mutect2, varscan2
- VWA3B | c.3787G>A p.A1263T | Missense Mutation (SNP) | VAF 70/132 reads (53%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.003); catalogued as COSV71376124; called by muse, mutect2, varscan2
- WDR6 | c.2421dup p.R808Afs*3 | Frame Shift Ins (INS) | VAF 52/140 reads (37%) | catalogued as rs750038548; called by mutect2, varscan2
- WDR70 | c.1052G>A p.C351Y | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV54266439; called by muse, mutect2
- WDR90 | c.3983C>T p.T1328M | Missense Mutation (SNP) | VAF 45/113 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.337); catalogued as rs761884544, COSV53469911; called by muse, mutect2, varscan2
- WEE2 | c.1229G>A p.R410Q | Missense Mutation (SNP) | VAF 31/58 reads (53%) | SIFT tolerated (0.96); PolyPhen benign (0.015); catalogued as rs1006040516, COSV66879274; called by muse, mutect2, varscan2
- WNK4 | c.1822del p.V608Cfs*53 | Frame Shift Del (DEL) | VAF 68/196 reads (35%) | catalogued as rs762079039; called by pindel, varscan2
- XK | c.451dup p.Q151Pfs*48 | Frame Shift Ins (INS) | VAF 87/245 reads (36%) | catalogued as rs1556442199; called by mutect2, pindel, varscan2
- ZBTB8B | c.431C>T p.A144V | Missense Mutation (SNP) | VAF 66/190 reads (35%) | SIFT tolerated (0.41); PolyPhen benign (0.042); catalogued as rs534592445; called by muse, varscan2
- ZC3H13 | c.1429C>T p.R477W | Missense Mutation (SNP) | VAF 128/346 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs768273440, COSV54451024; called by muse, mutect2, varscan2
- ZC3H4 | c.1402G>A p.D468N | Missense Mutation (SNP) | VAF 22/201 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.632); catalogued as rs1283103416; called by muse, mutect2, varscan2
- ZDHHC11 | c.647C>T p.T216M | Missense Mutation (SNP) | VAF 47/189 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs758425963; called by muse, mutect2, varscan2
- ZFHX3 | c.7666del p.A2556Rfs*56 | Frame Shift Del (DEL) | VAF 98/268 reads (37%) | catalogued as COSV51713933, COSV51742232, COSV51742433; called by mutect2, pindel, varscan2
- ZFP14 | c.634C>T p.R212C | Missense Mutation (SNP) | VAF 66/160 reads (41%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs767258236, COSV54204737; called by muse, mutect2, varscan2
- ZFP36L2 | c.683del p.G228Afs*233 | Frame Shift Del (DEL) | VAF 118/318 reads (37%) | catalogued as COSV99144234; called by mutect2, pindel, varscan2
- ZFP90 | c.1780del p.T594Pfs*57 | Frame Shift Del (DEL) | VAF 44/102 reads (43%) | catalogued as rs747260313; called by mutect2, varscan2
- ZFR | c.1570G>A p.E524K | Missense Mutation (SNP) | VAF 60/141 reads (43%) | SIFT tolerated (0.34); PolyPhen benign (0.08); catalogued as rs1427030825, COSV54053665; called by muse, mutect2, varscan2
- ZNF469 | c.8063C>T p.A2688V (on ENST00000437464; = p.A2716V on NM_001367624.2) | Missense Mutation (SNP) | VAF 104/262 reads (40%) | SIFT tolerated (0.37); PolyPhen benign (0.076); catalogued as rs1363001704; called by muse, mutect2, varscan2
- ZNF543 | c.1469G>A p.R490H | Missense Mutation (SNP) | VAF 59/168 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.312); catalogued as rs1007275172, COSV58628590; called by muse, mutect2, varscan2
- ZNF559 | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as COSV57836311, COSV57837320; called by muse, mutect2, varscan2
- ZNF592 | c.631C>G p.P211A | Missense Mutation (SNP) | VAF 105/256 reads (41%) | SIFT tolerated (0.71); PolyPhen benign (0.022); catalogued as COSV100246046; called by muse, mutect2, varscan2
- ZNF668 | c.1708C>T p.R570C | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as rs763330703, COSV56213868; called by muse, mutect2
- ZSCAN10 | c.1738C>T p.R580C (on ENST00000252463; = p.R635C on NM_032805.3) | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.019); catalogued as rs1326207066; called by muse, mutect2
- ACSL6 | c.799C>T p.P267S (on ENST00000379240; = p.P292S on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 69/187 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ADIG | c.76G>A p.G26S | Missense Mutation (SNP) | VAF 67/168 reads (40%) | SIFT tolerated (0.47); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- AGER | c.1033C>A p.L345M | Missense Mutation (SNP) | VAF 44/105 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- AMH | c.1100C>T p.T367M | Missense Mutation (SNP) | VAF 8/121 reads (7%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.47); called by muse, mutect2
- AMOT | c.2831C>T p.A944V (on ENST00000371959 / NM_001113490.1; = p.A535V on NM_133265.3) | Missense Mutation (SNP) | VAF 68/185 reads (37%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- AMPD2 | c.1252G>A p.V418M | Missense Mutation (SNP) | VAF 35/69 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- ANK3 | c.9993dup p.Y3332Ifs*11 | Frame Shift Ins (INS) | VAF 74/221 reads (33%) | called by mutect2, pindel, varscan2
- ANKRD12 | c.2949del p.K983Nfs*4 | Frame Shift Del (DEL) | VAF 36/82 reads (44%) | called by mutect2, varscan2
- ANKRD28 | c.244G>T p.V82F | Missense Mutation (SNP) | VAF 82/194 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- APBA3 | c.65G>T p.R22M | Missense Mutation (SNP) | VAF 73/176 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- ARHGEF25 | c.1354G>A p.A452T | Missense Mutation (SNP) | VAF 61/119 reads (51%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARHGEF6 | c.1185+2T>C p.X395_splice | Splice Site (SNP) | VAF 57/134 reads (43%) | called by muse, mutect2, varscan2
- ARID1A | c.4555del p.Q1519Rfs*8 | Frame Shift Del (DEL) | VAF 54/168 reads (32%) | called by mutect2, pindel, varscan2
- ARID5B | c.1489dup p.I497Nfs*31 | Frame Shift Ins (INS) | VAF 34/90 reads (38%) | called by mutect2, varscan2
- ASAP1 | c.2449A>T p.S817C | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- ASB14 | c.740_741del p.S247* | Frame Shift Del (DEL) | VAF 40/109 reads (37%) | called by pindel, varscan2
- ATP13A2 | c.2962G>T p.G988* | Nonsense Mutation (SNP) | VAF 140/345 reads (41%) | called by muse, mutect2
- ATP2A1 | c.1820T>C p.V607A | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- ATP5PB | c.471G>T p.Q157H | Missense Mutation (SNP) | VAF 54/189 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- B3GNTL1 | c.1065G>T p.Q355H | Missense Mutation (SNP) | VAF 7/174 reads (4%) | SIFT tolerated (0.25); PolyPhen benign (0.023); called by muse, mutect2
- BICRA | c.4576G>A p.A1526T | Missense Mutation (SNP) | VAF 52/138 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- BRCA2 | c.2132G>A p.C711Y | Missense Mutation (SNP) | VAF 12/295 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.11); called by muse, mutect2
- BTRC | c.343A>G p.T115A (on ENST00000370187 / NM_033637.4; = p.T79A on NM_003939.5) | Missense Mutation (SNP) | VAF 66/165 reads (40%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- C15orf39 | c.2301del p.F767Lfs*28 | Frame Shift Del (DEL) | VAF 77/203 reads (38%) | called by mutect2, pindel, varscan2
- C1R | c.689del p.P230Lfs*100 (on ENST00000536053 / NM_001354346.2; = p.P216Lfs*100 on NM_001733.7) | Frame Shift Del (DEL) | VAF 21/58 reads (36%) | called by mutect2, pindel, varscan2
- C1orf159 | c.97A>G p.I33V | Missense Mutation (SNP) | VAF 44/116 reads (38%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- CADM4 | c.1011_1013del p.I338del | In Frame Del (DEL) | VAF 80/216 reads (37%) | called by mutect2, pindel, varscan2
- CASP8AP2 | c.3800del p.N1267Tfs*6 | Frame Shift Del (DEL) | VAF 79/218 reads (36%) | called by mutect2, pindel, varscan2
- CATSPER4 | c.997G>A p.E333K | Missense Mutation (SNP) | VAF 68/186 reads (37%) | SIFT tolerated (0.26); PolyPhen benign (0.007); called by muse, mutect2
- CCDC168 | c.14427_14428del p.R4809Sfs*29 | Frame Shift Del (DEL) | VAF 44/131 reads (34%) | called by pindel, varscan2
- CCDC83 | c.961C>T p.H321Y (on ENST00000342404 / NM_001286159.2; = p.H352Y on NM_173556.5) | Missense Mutation (SNP) | VAF 74/167 reads (44%) | SIFT tolerated (0.47); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CCDC96 | c.302C>T p.A101V | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- CCIN | c.1411C>T p.L471F | Missense Mutation (SNP) | VAF 121/290 reads (42%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- CDH6 | c.2068A>G p.R690G | Missense Mutation (SNP) | VAF 89/211 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CDK13 | c.2344_2346del p.K782del | In Frame Del (DEL) | VAF 32/90 reads (36%) | called by pindel, varscan2
- CDS1 | c.297del p.L99Ffs*4 | Frame Shift Del (DEL) | VAF 46/169 reads (27%) | called by mutect2, pindel, varscan2
- CELSR2 | c.6642dup p.V2215Rfs*30 | Frame Shift Ins (INS) | VAF 19/56 reads (34%) | called by mutect2, pindel, varscan2
- CFH | c.1025G>A p.R342K | Missense Mutation (SNP) | VAF 86/243 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- CIC | c.363G>T p.K121N | Missense Mutation (SNP) | VAF 101/222 reads (45%) | SIFT tolerated, low confidence (0.19); PolyPhen probably damaging (0.981); called by mutect2, varscan2
- CLCN6 | c.1613T>C p.I538T | Missense Mutation (SNP) | VAF 42/98 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- CMSS1 | c.768G>T p.E256D | Missense Mutation (SNP) | VAF 46/115 reads (40%) | SIFT tolerated (0.74); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- COL22A1 | c.217G>A p.D73N | Missense Mutation (SNP) | VAF 44/109 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- COL4A6 | c.1076-1G>T p.X359_splice | Splice Site (SNP) | VAF 35/75 reads (47%) | called by muse, mutect2, varscan2
- CPNE8 | c.106_108del p.L36del | In Frame Del (DEL) | VAF 38/108 reads (35%) | called by pindel, varscan2
- CSMD1 | c.4127_4129del p.S1376del (on ENST00000520002; = p.S1375del on NM_033225.6) | In Frame Del (DEL) | VAF 67/173 reads (39%) | called by mutect2, pindel, varscan2
- CYP1B1 | c.482G>A p.R161H | Missense Mutation (SNP) | VAF 12/258 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.026); called by muse, mutect2
- DDX27 | c.961T>C p.C321R | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- DDX5 | c.1708G>T p.G570C | Missense Mutation (SNP) | VAF 8/142 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.905); called by muse, mutect2
- DENND2B | c.218del p.P73Qfs*53 | Frame Shift Del (DEL) | VAF 25/70 reads (36%) | called by mutect2, pindel, varscan2
- DHODH | c.56del p.G19Efs*10 | Frame Shift Del (DEL) | VAF 65/149 reads (44%) | called by mutect2, varscan2
- DHX40 | c.1097T>A p.V366E | Missense Mutation (SNP) | VAF 82/208 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- DIAPH3 | c.1880T>C p.L627P (on ENST00000400324 / NM_001042517.2; = p.L364P on NM_030932.3) | Missense Mutation (SNP) | VAF 66/154 reads (43%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- DLGAP2 | c.2767C>T p.Q923* | Nonsense Mutation (SNP) | VAF 58/170 reads (34%) | called by muse, mutect2, varscan2
- DLGAP3 | c.1342del p.R448Gfs*20 | Frame Shift Del (DEL) | VAF 68/206 reads (33%) | called by pindel, varscan2
- DOCK3 | c.5378C>T p.A1793V | Missense Mutation (SNP) | VAF 19/244 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.516); called by muse, mutect2
- DPY19L2 | c.238G>A p.G80S | Missense Mutation (SNP) | VAF 100/229 reads (44%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- EDNRB | c.274C>T p.Q92* (on ENST00000377211 / NM_001201397.1; = p.Q2* on NM_000115.5) | Nonsense Mutation (SNP) | VAF 17/41 reads (41%) | called by muse, mutect2, varscan2
- EHBP1 | c.3185T>C p.V1062A | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- ENDOD1 | c.196G>A p.A66T | Missense Mutation (SNP) | VAF 49/103 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- EPHA8 | c.1802del p.P601Rfs*82 | Frame Shift Del (DEL) | VAF 35/75 reads (47%) | called by mutect2, pindel, varscan2
- EXOC4 | c.1918G>A p.A640T | Missense Mutation (SNP) | VAF 58/157 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- FAM110B | c.586G>A p.V196M | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.613); called by muse, mutect2, varscan2
- FAM135A | c.2371A>G p.T791A (on ENST00000370479 / NM_001351599.1; = p.T578A on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 44/121 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM155B | c.24G>A p.W8* | Nonsense Mutation (SNP) | VAF 69/167 reads (41%) | called by muse, varscan2
- FAM168A | c.366del p.Y123Tfs*89 (on ENST00000064778 / NM_001286050.2; = p.Y114Tfs*89 on NM_015159.3) | Frame Shift Del (DEL) | VAF 43/142 reads (30%) | called by mutect2, pindel, varscan2
- FAM217A | c.319T>A p.S107T | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- FAM76B | c.100G>A p.A34T | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.236); called by muse, mutect2, varscan2
- FBXW10 | c.2952G>T p.E984D | Missense Mutation (SNP) | VAF 159/384 reads (41%) | SIFT tolerated (0.28); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- FCSK | c.953T>C p.M318T | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.38); PolyPhen benign (0.089); called by muse, varscan2
- FGA | c.1706A>G p.E569G | Missense Mutation (SNP) | VAF 140/369 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- FGL1 | c.314del p.P105Qfs*18 | Frame Shift Del (DEL) | VAF 34/89 reads (38%) | called by mutect2, pindel, varscan2
- FGR | c.142G>A p.A48T | Missense Mutation (SNP) | VAF 82/219 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FIBCD1 | c.743T>C p.L248P | Missense Mutation (SNP) | VAF 76/163 reads (47%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- FOXD4L5 | c.632dup p.A213Sfs*175 | Frame Shift Ins (INS) | VAF 17/145 reads (12%) | called by mutect2, pindel, varscan2
- FOXJ1 | c.867del p.S290Afs*43 | Frame Shift Del (DEL) | VAF 27/82 reads (33%) | called by mutect2, pindel, varscan2
- FOXL1 | c.501G>T p.E167D | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- FUNDC2 | c.285G>A p.W95* | Nonsense Mutation (SNP) | VAF 61/153 reads (40%) | called by muse, mutect2, varscan2
- FXR1 | c.893G>A p.G298E | Missense Mutation (SNP) | VAF 43/94 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GK | c.205G>T p.E69* | Nonsense Mutation (SNP) | VAF 10/252 reads (4%) | called by muse, mutect2
- GPR25 | c.149dup p.A51Rfs*35 | Frame Shift Ins (INS) | VAF 45/129 reads (35%) | called by mutect2, pindel, varscan2
- GPR37 | c.787G>A p.A263T | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- GTF3C4 | c.722G>T p.R241M | Missense Mutation (SNP) | VAF 99/215 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HBE1 | c.73G>T p.G25* | Nonsense Mutation (SNP) | VAF 6/132 reads (5%) | called by muse, mutect2
- HDAC7 | c.2304del p.M769Wfs*12 (on ENST00000427332; = p.M808Wfs*12 on NM_015401.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 52/161 reads (32%) | called by mutect2, pindel, varscan2
- HNRNPM | c.1331T>C p.M444T | Missense Mutation (SNP) | VAF 74/195 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- HYOU1 | c.45T>A p.C15* | Nonsense Mutation (SNP) | VAF 35/260 reads (13%) | called by muse, mutect2, varscan2
- ICE1 | c.3778_3781del p.S1260Rfs*3 | Frame Shift Del (DEL) | VAF 33/103 reads (32%) | called by pindel, varscan2
- IFT122 | c.2599C>T p.P867S (on ENST00000348417 / NM_052989.3; = p.P808S on NM_018262.4) | Missense Mutation (SNP) | VAF 20/352 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- IGF2R | c.6932G>A p.S2311N | Missense Mutation (SNP) | VAF 52/120 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- IL6ST | c.1807G>T p.G603C | Missense Mutation (SNP) | VAF 56/145 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KAT2B | c.2220G>T p.K740N | Missense Mutation (SNP) | VAF 64/164 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- KBTBD4 | c.674_675del p.E225Vfs*38 | Frame Shift Del (DEL) | VAF 62/185 reads (34%) | called by pindel, varscan2
- KCNA4 | c.663dup p.D222* | Frame Shift Ins (INS) | VAF 70/205 reads (34%) | called by mutect2, varscan2
- KEAP1 | c.92T>C p.V31A | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIAA2026 | c.4481C>A p.P1494H | Missense Mutation (SNP) | VAF 50/124 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- KIF20B | c.3223del p.S1075Vfs*18 (on ENST00000371728 / NM_001284259.2; = p.S1035Vfs*18 on NM_016195.4) | Frame Shift Del (DEL) | VAF 74/237 reads (31%) | called by pindel, varscan2
- KRTAP10-7 | c.312del p.C105Afs*75 | Frame Shift Del (DEL) | VAF 55/301 reads (18%) | called by mutect2, pindel, varscan2
- KRTAP4-6 | c.488G>A p.C163Y | Missense Mutation (SNP) | VAF 102/538 reads (19%) | SIFT tolerated (0.55); called by muse, mutect2
- LAMB3 | c.3496C>T p.L1166F | Missense Mutation (SNP) | VAF 22/142 reads (15%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- LAMC3 | c.2370T>A p.D790E | Missense Mutation (SNP) | VAF 10/193 reads (5%) | SIFT tolerated (0.28); PolyPhen benign (0.015); called by muse, mutect2
- MALT1 | c.1691T>C p.I564T | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT deleterious (0.04); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- MAP1S | c.593del p.P198Rfs*93 | Frame Shift Del (DEL) | VAF 44/117 reads (38%) | called by mutect2, pindel, varscan2
- MAP3K10 | c.2775del p.S926Afs*78 | Frame Shift Del (DEL) | VAF 93/211 reads (44%) | called by mutect2, varscan2
- MASP1 | c.2006del p.G669Vfs*29 | Frame Shift Del (DEL) | VAF 74/202 reads (37%) | called by mutect2, pindel, varscan2
- MAST1 | c.2218C>A p.P740T | Missense Mutation (SNP) | VAF 89/205 reads (43%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- MED13 | c.693del p.K231Nfs*2 | Frame Shift Del (DEL) | VAF 90/224 reads (40%) | called by mutect2, varscan2
- MED7 | c.632G>T p.R211M | Missense Mutation (SNP) | VAF 55/142 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- METTL17 | c.377C>T p.T126I | Missense Mutation (SNP) | VAF 48/158 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- MEX3C | c.929dup p.N310Kfs*11 | Frame Shift Ins (INS) | VAF 63/159 reads (40%) | called by mutect2, pindel, varscan2
- MFN1 | c.524T>C p.V175A | Missense Mutation (SNP) | VAF 48/107 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MIGA1 | c.1188+10del | Splice Region (DEL) | VAF 17/68 reads (25%) | called by mutect2, pindel, varscan2
- MIS18BP1 | c.196del p.M66* | Frame Shift Del (DEL) | VAF 33/87 reads (38%) | called by mutect2, pindel, varscan2
- MOGAT3 | c.952G>A p.A318T | Missense Mutation (SNP) | VAF 60/167 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- MORC4 | c.2799T>G p.N933K | Missense Mutation (SNP) | VAF 42/92 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); called by muse, varscan2
- MRGPRX1 | c.98T>C p.L33P | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- MRPS30 | c.*4del | Frame Shift Del (DEL) | VAF 24/61 reads (39%) | called by mutect2, pindel, varscan2
- MTMR4 | c.1204C>T p.P402S | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MUC17 | c.12521G>A p.S4174N | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MUC4 | c.3083C>T p.T1028I | Missense Mutation (SNP) | VAF 72/269 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.517); called by muse, mutect2, varscan2
- MUC6 | c.4718del p.F1573Sfs*19 | Frame Shift Del (DEL) | VAF 35/200 reads (18%) | called by mutect2, pindel, varscan2
- MYH7 | c.4730C>T p.A1577V | Missense Mutation (SNP) | VAF 46/106 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MYH7 | c.3035C>T p.A1012V | Missense Mutation (SNP) | VAF 61/275 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NAA25 | c.776del p.N259Tfs*9 | Frame Shift Del (DEL) | VAF 36/104 reads (35%) | called by mutect2, pindel, varscan2
- NCBP1 | c.1756G>A p.V586M | Missense Mutation (SNP) | VAF 43/135 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- NCDN | c.1766C>T p.T589I | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.746); called by mutect2, varscan2
- NDC1 | c.1640C>T p.P547L | Missense Mutation (SNP) | VAF 59/131 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NDST4 | c.526C>A p.Q176K | Missense Mutation (SNP) | VAF 58/159 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- NEDD4 | c.3473G>A p.W1158* (on ENST00000508342 / NM_001284338.1; = p.W739* on NM_006154.4) | Nonsense Mutation (SNP) | VAF 32/90 reads (36%) | called by muse, mutect2, varscan2
- NFIB | c.540G>T p.L180F | Missense Mutation (SNP) | VAF 40/112 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- NHLH2 | c.403del p.V135Cfs*122 | Frame Shift Del (DEL) | VAF 95/243 reads (39%) | called by mutect2, pindel, varscan2
- NIBAN3 | c.1588T>A p.W530R | Missense Mutation (SNP) | VAF 52/116 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- NKAP | c.1207G>T p.E403* | Nonsense Mutation (SNP) | VAF 79/206 reads (38%) | called by muse, mutect2, varscan2
- NLGN3 | c.335C>T p.T112I | Missense Mutation (SNP) | VAF 74/142 reads (52%) | SIFT tolerated (0.11); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- NODAL | c.19C>T p.Q7* | Nonsense Mutation (SNP) | VAF 65/192 reads (34%) | called by muse, mutect2, varscan2
- NOL11 | c.604T>G p.S202A | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT tolerated (0.24); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- NRXN2 | c.1292del p.G431Afs*46 | Frame Shift Del (DEL) | VAF 108/242 reads (45%) | called by mutect2, varscan2
- NXPE3 | c.1367A>G p.Y456C | Missense Mutation (SNP) | VAF 89/215 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- OBSCN | c.21210del p.L7071* | Frame Shift Del (DEL) | VAF 27/141 reads (19%) | called by mutect2, pindel, varscan2
- OR5K3 | c.205A>C p.M69L | Missense Mutation (SNP) | VAF 105/270 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PAN3 | c.1955C>T p.T652I | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.84); called by mutect2, varscan2
- PASK | c.2767_2768del p.L923Vfs*37 | Frame Shift Del (DEL) | VAF 100/272 reads (37%) | called by pindel, varscan2
- PAXIP1 | c.1660G>A p.A554T | Missense Mutation (SNP) | VAF 44/104 reads (42%) | SIFT tolerated (0.6); PolyPhen benign (0.007); called by muse, varscan2
- PCDHGA7 | c.1495dup p.A499Gfs*12 | Frame Shift Ins (INS) | VAF 85/217 reads (39%) | called by mutect2, pindel, varscan2
- PCDHGB1 | c.1874C>T p.A625V | Missense Mutation (SNP) | VAF 58/188 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.477); called by muse, mutect2, varscan2
- PCDHGB6 | c.641C>T p.A214V | Missense Mutation (SNP) | VAF 58/157 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCNT | c.2201C>T p.A734V | Missense Mutation (SNP) | VAF 42/126 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- PCNX2 | c.2666A>C p.Q889P | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- PCNX4 | c.2811G>A p.W937* (on ENST00000406854 / NM_001330177.2; = p.W703* on NM_022495.5) | Nonsense Mutation (SNP) | VAF 68/162 reads (42%) | called by muse, mutect2, varscan2
- PEG3 | c.290T>C p.I97T | Missense Mutation (SNP) | VAF 59/159 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PGM5 | c.174G>T p.Q58H | Missense Mutation (SNP) | VAF 50/207 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PHKG1 | c.827G>A p.R276H | Missense Mutation (SNP) | VAF 54/118 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PILRB | c.124T>C p.S42P | Missense Mutation (SNP) | VAF 66/173 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PKP3 | c.2334_2336del p.N778del | In Frame Del (DEL) | VAF 56/170 reads (33%) | called by pindel, varscan2
- PLA2G4C | c.995C>T p.P332L | Missense Mutation (SNP) | VAF 62/160 reads (39%) | SIFT tolerated (0.42); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- PLEKHA2 | c.995G>A p.C332Y | Missense Mutation (SNP) | VAF 12/296 reads (4%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2
- PLS3 | c.1636-2A>G p.X546_splice | Splice Site (SNP) | VAF 6/122 reads (5%) | called by muse, mutect2
- PMS1 | c.1913C>T p.A638V | Missense Mutation (SNP) | VAF 68/167 reads (41%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); called by muse, varscan2
- PODN | c.1232C>T p.T411M (on ENST00000395871; = p.T363M on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/214 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2
- POLE | c.1061C>T p.T354I | Missense Mutation (SNP) | VAF 48/124 reads (39%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PPIL1 | c.206G>T p.G69V | Missense Mutation (SNP) | VAF 58/169 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, varscan2
- PPP1R13B | c.1633C>T p.P545S | Missense Mutation (SNP) | VAF 105/285 reads (37%) | SIFT tolerated (0.37); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- PRAMEF15 | c.1255dup p.R419Pfs*7 | Frame Shift Ins (INS) | VAF 60/564 reads (11%) | called by mutect2, pindel
- PRLH | c.73A>G p.T25A | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PSMB4 | c.55G>T p.G19* | Nonsense Mutation (SNP) | VAF 66/176 reads (38%) | called by muse, mutect2
- PXDNL | c.1358C>A p.T453K | Missense Mutation (SNP) | VAF 67/168 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.444); called by mutect2, varscan2
- RAB5C | c.633C>A p.S211R | Missense Mutation (SNP) | VAF 75/166 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- RAB9A | c.24del p.F8Lfs*3 | Frame Shift Del (DEL) | VAF 33/68 reads (49%) | called by mutect2, pindel, varscan2
- RALY | c.448G>A p.V150I (on ENST00000246194 / NM_016732.3; = p.V134I on NM_007367.4) | Missense Mutation (SNP) | VAF 57/122 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- RBBP6 | c.3625del p.I1209Sfs*47 | Frame Shift Del (DEL) | VAF 76/201 reads (38%) | called by mutect2, pindel, varscan2
- RBM6 | c.293del p.G98Efs*56 | Frame Shift Del (DEL) | VAF 70/184 reads (38%) | called by mutect2, varscan2
- RDH10 | c.124A>G p.T42A | Missense Mutation (SNP) | VAF 15/150 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- REC8 | c.62C>T p.A21V | Missense Mutation (SNP) | VAF 62/129 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); called by muse, mutect2, varscan2
- RELN | c.3238G>A p.E1080K | Missense Mutation (SNP) | VAF 146/407 reads (36%) | SIFT tolerated (0.56); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- REPS2 | c.1280-1G>A p.X427_splice | Splice Site (SNP) | VAF 42/109 reads (39%) | called by muse, mutect2, varscan2
- RET | c.56T>C p.L19P | Missense Mutation (SNP) | VAF 46/143 reads (32%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- RNF220 | c.249del p.F83Lfs*22 | Frame Shift Del (DEL) | VAF 57/147 reads (39%) | called by mutect2, pindel, varscan2
- RPN2 | c.1393A>G p.T465A | Missense Mutation (SNP) | VAF 117/281 reads (42%) | SIFT tolerated (0.34); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- SALL3 | c.3653C>T p.A1218V | Missense Mutation (SNP) | VAF 96/225 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- SCAF1 | c.3540del p.T1181Pfs*28 | Frame Shift Del (DEL) | VAF 23/63 reads (37%) | called by mutect2, varscan2
- SCAF4 | c.359del p.N120Mfs*25 | Frame Shift Del (DEL) | VAF 70/199 reads (35%) | called by mutect2, pindel, varscan2
- SCNN1B | c.745T>C p.C249R | Missense Mutation (SNP) | VAF 120/274 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- SEM1 | c.110A>G p.H37R | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.537); called by muse, mutect2, varscan2
- SEPHS1 | c.1010G>A p.C337Y | Missense Mutation (SNP) | VAF 77/180 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SETD1B | c.2645G>A p.R882H | Missense Mutation (SNP) | VAF 76/146 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SF3B2 | c.793G>A p.V265M | Missense Mutation (SNP) | VAF 67/174 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.56); called by muse, mutect2, varscan2
- SIPA1 | c.746A>C p.E249A | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- SIPA1L1 | c.509T>C p.I170T | Missense Mutation (SNP) | VAF 69/170 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- SLC10A4 | c.277G>A p.A93T | Missense Mutation (SNP) | VAF 43/91 reads (47%) | SIFT tolerated (0.54); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SLC17A1 | c.829T>C p.S277P | Missense Mutation (SNP) | VAF 49/136 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SLC2A7 | c.47A>G p.E16G | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.143); called by mutect2, varscan2
- SLC4A2 | c.188G>A p.G63D | Missense Mutation (SNP) | VAF 50/100 reads (50%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- SLF1 | c.2667A>C p.E889D | Missense Mutation (SNP) | VAF 54/105 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- SLMAP | c.608G>A p.S203N | Missense Mutation (SNP) | VAF 50/123 reads (41%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SMC2 | c.820del p.I274* | Frame Shift Del (DEL) | VAF 51/141 reads (36%) | called by mutect2, pindel, varscan2
- SPNS1 | c.1435C>G p.L479V | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- SPRED1 | c.1153G>T p.G385* | Nonsense Mutation (SNP) | VAF 115/290 reads (40%) | called by muse, mutect2, varscan2
- STIP1 | c.1136C>A p.A379D | Missense Mutation (SNP) | VAF 9/96 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2
- SYT7 | c.109C>A p.L37I | Missense Mutation (SNP) | VAF 68/160 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TAF1C | c.2120del p.P707Lfs*7 | Frame Shift Del (DEL) | VAF 25/66 reads (38%) | called by mutect2, pindel, varscan2
- TBC1D9B | c.1416+1del p.X472_splice | Splice Site (DEL) | VAF 41/299 reads (14%) | called by mutect2, pindel, varscan2
- TEX26 | c.162A>T p.R54S | Missense Mutation (SNP) | VAF 42/88 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- TFAM | c.628C>A p.R210S | Missense Mutation (SNP) | VAF 71/211 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TFAP2B | c.321del p.Q108Nfs*83 | Frame Shift Del (DEL) | VAF 72/217 reads (33%) | called by mutect2, pindel, varscan2
- TGFB2 | c.194del p.P65Rfs*3 | Frame Shift Del (DEL) | VAF 75/188 reads (40%) | called by mutect2, pindel, varscan2
- THSD7B | c.329A>G p.D110G | Missense Mutation (SNP) | VAF 78/191 reads (41%) | SIFT tolerated (0.36); PolyPhen benign (0.287); called by muse, mutect2, varscan2
- TLN2 | c.38G>A p.C13Y | Missense Mutation (SNP) | VAF 79/176 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- TM6SF1 | c.1007del p.L336* | Frame Shift Del (DEL) | VAF 54/168 reads (32%) | called by pindel, varscan2
- TMC8 | c.577C>T p.P193S | Missense Mutation (SNP) | VAF 169/384 reads (44%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- TMEM161B | c.533dup p.F179Lfs*20 | Frame Shift Ins (INS) | VAF 54/146 reads (37%) | called by mutect2, varscan2
- TMTC1 | c.1991G>A p.G664E (on ENST00000539277 / NM_001193451.2; = p.G556E on NM_175861.3) | Missense Mutation (SNP) | VAF 59/116 reads (51%) | SIFT tolerated (0.05); PolyPhen benign (0.359); called by muse, mutect2, varscan2
- TNFRSF6B | c.403G>T p.G135C | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TNXB | c.1511G>A p.R504H | Missense Mutation (SNP) | VAF 9/142 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.052); called by muse, mutect2
- TPH1 | c.373T>C p.Y125H | Missense Mutation (SNP) | VAF 92/244 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, varscan2
- TRIM29 | c.569G>A p.C190Y | Missense Mutation (SNP) | VAF 68/161 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TSPAN3 | c.67del p.A23Qfs*33 | Frame Shift Del (DEL) | VAF 16/60 reads (27%) | called by pindel, varscan2
- TXNDC11 | c.2744T>G p.L915R (on ENST00000356957 / NM_001303447.2; = p.L888R on NM_015914.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TYW3 | c.664del p.R222Efs*27 | Frame Shift Del (DEL) | VAF 64/203 reads (32%) | called by mutect2, pindel, varscan2
- UBR4 | c.9058del p.A3020Pfs*2 | Frame Shift Del (DEL) | VAF 53/179 reads (30%) | called by mutect2, pindel, varscan2
- UMOD | c.1912A>G p.T638A | Missense Mutation (SNP) | VAF 126/318 reads (40%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- VARS2 | c.1156G>A p.V386M | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- WDR89 | c.315A>C p.K105N | Missense Mutation (SNP) | VAF 57/146 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- WIZ | c.1767del p.Y590Tfs*37 | Frame Shift Del (DEL) | VAF 18/55 reads (33%) | called by mutect2, pindel, varscan2
- WTAP | c.1162A>G p.S388G | Missense Mutation (SNP) | VAF 46/92 reads (50%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); called by muse, mutect2
- XRCC2 | c.350del p.L117Wfs*17 | Frame Shift Del (DEL) | VAF 41/100 reads (41%) | called by mutect2, varscan2
- XYLT2 | c.1339G>T p.A447S | Missense Mutation (SNP) | VAF 51/107 reads (48%) | SIFT tolerated (0.39); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- YBX2 | c.344C>T p.T115I | Missense Mutation (SNP) | VAF 43/145 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- YLPM1 | c.761del p.P254Lfs*35 | Frame Shift Del (DEL) | VAF 76/217 reads (35%) | called by mutect2, pindel, varscan2
- ZBTB20 | c.2075del p.P692Lfs*43 (on ENST00000474710 / NM_001164342.2; = p.P619Lfs*43 on NM_015642.6 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 38/114 reads (33%) | called by mutect2, pindel
- ZDHHC21 | c.494del p.K165Sfs*15 | Frame Shift Del (DEL) | VAF 59/120 reads (49%) | called by mutect2, pindel, varscan2
- ZFHX4 | c.6170del p.P2057Hfs*26 | Frame Shift Del (DEL) | VAF 30/78 reads (38%) | called by mutect2, varscan2
- ZFHX4 | c.7939dup p.R2647Kfs*29 | Frame Shift Ins (INS) | VAF 16/60 reads (27%) | called by mutect2, varscan2
- ZFP28 | c.64del p.R22Afs*12 | Frame Shift Del (DEL) | VAF 43/97 reads (44%) | called by mutect2, pindel, varscan2
- ZFP36L2 | c.1042del p.A348Pfs*113 | Frame Shift Del (DEL) | VAF 34/107 reads (32%) | called by mutect2, pindel, varscan2
- ZMYND10 | c.872del p.K291Sfs*27 | Frame Shift Del (DEL) | VAF 104/287 reads (36%) | called by mutect2, pindel, varscan2
- ZNF462 | c.4307C>A p.P1436H | Missense Mutation (SNP) | VAF 97/217 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF507 | c.1309G>T p.G437* | Nonsense Mutation (SNP) | VAF 15/236 reads (6%) | called by muse, mutect2
- ZNF516 | c.1624C>T p.R542C | Missense Mutation (SNP) | VAF 59/123 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF691 | c.874T>C p.F292L (on ENST00000372502; = p.F261L on NM_015911.3) | Missense Mutation (SNP) | VAF 62/157 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNFX1 | c.1201A>G p.R401G | Missense Mutation (SNP) | VAF 65/139 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.476); called by muse, mutect2, varscan2
- ZSWIM3 | c.1538A>T p.E513V | Missense Mutation (SNP) | VAF 84/214 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- ZSWIM4 | c.971C>T p.A324V | Missense Mutation (SNP) | VAF 7/120 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0.122); called by muse, mutect2
- AATK | c.975G>T p.V325= (on ENST00000326724 / NM_001080395.3; = p.V222= on NM_004920.2) | Silent (SNP) | VAF 8/18 reads (44%) | called by muse, mutect2, varscan2
- ACACB | c.81G>A p.T27= | Silent (SNP) | VAF 75/175 reads (43%) | catalogued as rs760884462, COSV58137732; called by muse, mutect2, varscan2
- ACSS3 | c.132C>T p.G44= | Silent (SNP) | VAF 64/144 reads (44%) | catalogued as rs890772833; called by muse, mutect2, varscan2
- ADRA1B | c.522C>T p.T174= | Silent (SNP) | VAF 93/216 reads (43%) | catalogued as rs1267090803; called by muse, mutect2, varscan2
- AMER2 | c.870C>T p.P290= | Silent (SNP) | VAF 17/32 reads (53%) | catalogued as rs946327141; called by muse, mutect2, varscan2
- APOE | c.666G>A p.Q222= | Silent (SNP) | VAF 47/140 reads (34%) | called by muse, mutect2, varscan2
- ARHGAP36 | c.531G>A p.R177= | Silent (SNP) | VAF 90/188 reads (48%) | called by muse, mutect2, varscan2
- ARSD | c.789C>T p.D263= | Silent (SNP) | VAF 76/154 reads (49%) | catalogued as rs765200568; called by muse, mutect2, varscan2
- ATP2A3 | c.243C>T p.G81= | Silent (SNP) | VAF 92/234 reads (39%) | catalogued as rs771321946; called by muse, mutect2, varscan2
- BCKDHB | c.372G>A p.L124= | Silent (SNP) | VAF 90/202 reads (45%) | catalogued as COSV57514964; called by muse, mutect2, varscan2
- BCL11B | c.939G>A p.T313= (on ENST00000357195 / NM_001282237.2; = p.T242= on NM_022898.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/17 reads (53%) | catalogued as rs368688713; called by muse, mutect2, varscan2
- BTNL9 | c.1314C>T p.V438= | Silent (SNP) | VAF 42/111 reads (38%) | catalogued as rs1036370599, COSV59797772; called by muse, mutect2, varscan2
- C11orf96 | c.126C>T p.S42= | Silent (SNP) | VAF 43/97 reads (44%) | called by muse, mutect2, varscan2
- CCDC166 | c.153C>T p.S51= | Silent (SNP) | VAF 70/157 reads (45%) | called by muse, mutect2, varscan2
- CCHCR1 | c.675C>T p.A225= | Silent (SNP) | VAF 48/116 reads (41%) | catalogued as rs767710720; called by muse, mutect2, varscan2
- CCT8L2 | c.42G>A p.R14= | Silent (SNP) | VAF 42/102 reads (41%) | catalogued as rs1409205136, COSV100742867; called by muse, mutect2, varscan2
- CEACAM3 | c.69A>G p.S23= | Silent (SNP) | VAF 24/68 reads (35%) | called by muse, mutect2
- CELSR1 | c.6606G>A p.A2202= | Silent (SNP) | VAF 36/97 reads (37%) | catalogued as rs769151042; called by muse, mutect2, varscan2
- CHD6 | c.6708C>T p.S2236= | Silent (SNP) | VAF 8/241 reads (3%) | catalogued as rs951814095; called by muse, mutect2
- CHI3L2 | c.90T>G p.V30= | Silent (SNP) | VAF 52/132 reads (39%) | catalogued as COSV100869316; called by muse, mutect2, varscan2
- COL12A1 | c.8496A>G p.P2832= | Silent (SNP) | VAF 38/106 reads (36%) | called by muse, mutect2, varscan2
- COL3A1 | c.1860A>G p.P620= | Silent (SNP) | VAF 103/275 reads (37%) | called by muse, mutect2, varscan2
- CPLX2 | c.199C>A p.R67= | Silent (SNP) | VAF 34/67 reads (51%) | catalogued as rs1260048853; called by muse, mutect2, varscan2
- CREBBP | c.1500G>A p.L500= | Silent (SNP) | VAF 80/162 reads (49%) | called by muse, mutect2, varscan2
- DENND6B | c.234C>T p.Y78= | Silent (SNP) | VAF 88/240 reads (37%) | catalogued as rs963457806; called by muse, mutect2, varscan2
- DIP2B | c.1110A>G p.T370= | Silent (SNP) | VAF 8/162 reads (5%) | catalogued as COSV99999539; called by muse, mutect2
- DNAH10 | c.9390C>T p.A3130= (on ENST00000409039; = p.A3069= on NM_207437.3) | Silent (SNP) | VAF 36/90 reads (40%) | catalogued as rs370543140; called by muse, mutect2, varscan2
- DRC1 | c.1977G>A p.S659= | Silent (SNP) | VAF 65/186 reads (35%) | catalogued as rs368854171; called by muse, mutect2, varscan2
- DUSP8 | c.138C>T p.S46= | Silent (SNP) | VAF 42/110 reads (38%) | catalogued as rs1040325649; called by muse, mutect2, varscan2
- EDNRA | c.852C>T p.N284= | Silent (SNP) | VAF 23/179 reads (13%) | catalogued as rs1265027525; called by muse, mutect2, varscan2
- ENO4 | c.672G>A p.A224= (on ENST00000622726; = p.A223= on NM_001242699.2) | Silent (SNP) | VAF 20/46 reads (43%) | catalogued as rs531071276; called by muse, mutect2
- EOLA1 | c.169C>T p.L57= | Silent (SNP) | VAF 68/182 reads (37%) | called by muse, mutect2, varscan2
- EPPIN | c.198A>G p.G66= | Silent (SNP) | VAF 45/121 reads (37%) | catalogued as COSV60548251, COSV60548497; called by muse, mutect2, varscan2
- ERVW-1 | c.957C>A p.P319= | Silent (SNP) | VAF 22/70 reads (31%) | catalogued as COSV71259357, COSV71259554; called by muse, mutect2, varscan2
- FBLN7 | c.726C>T p.H242= | Silent (SNP) | VAF 46/119 reads (39%) | catalogued as rs780033468, COSV99735044; called by muse, mutect2, varscan2
- FMO1 | c.1578T>C p.A526= | Silent (SNP) | VAF 4/12 reads (33%) | called by muse, varscan2
- FOXN3 | c.1173C>T p.S391= (on ENST00000261302; = p.S369= on NM_005197.4) | Silent (SNP) | VAF 51/114 reads (45%) | catalogued as rs778753018, COSV54318225; called by muse, mutect2, varscan2
- GABBR2 | c.885G>A p.T295= | Silent (SNP) | VAF 96/288 reads (33%) | catalogued as rs200940989; called by muse, varscan2
- GIGYF1 | c.2478C>T p.G826= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as rs779548243; called by muse, mutect2, varscan2
- GNG4 | c.198C>T p.R66= | Silent (SNP) | VAF 65/176 reads (37%) | catalogued as rs1037180132, COSV64000206; called by muse, mutect2, varscan2
- GPR25 | c.960C>T p.D320= | Silent (SNP) | VAF 79/188 reads (42%) | catalogued as rs1465450632; called by muse, mutect2, varscan2
- GREB1 | c.1510C>T p.L504= | Silent (SNP) | VAF 83/177 reads (47%) | catalogued as rs1434207712; called by muse, mutect2, varscan2
- GRID2IP | c.2349G>A p.A783= | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as rs1000104534; called by muse, mutect2, varscan2
- HCN3 | c.928C>T p.L310= | Silent (SNP) | VAF 74/158 reads (47%) | called by muse, mutect2, varscan2
- HERC2 | c.9969G>A p.A3323= | Silent (SNP) | VAF 50/162 reads (31%) | catalogued as rs532645243, COSV55335825; called by muse, mutect2, varscan2
- HOXA10 | c.399G>T p.P133= | Silent (SNP) | VAF 75/173 reads (43%) | called by muse, mutect2, varscan2
- IRX1 | c.441C>T p.N147= | Silent (SNP) | VAF 82/223 reads (37%) | catalogued as rs1402030815, COSV57360518, COSV57361673; called by muse, mutect2, varscan2
- KBTBD13 | c.732G>A p.P244= | Silent (SNP) | VAF 21/45 reads (47%) | catalogued as rs753042899; called by muse, mutect2, varscan2
- KCNJ4 | c.546G>A p.A182= | Silent (SNP) | VAF 42/96 reads (44%) | catalogued as rs201862614; called by muse, mutect2, varscan2
- KCNMB2 | c.171C>T p.C57= | Silent (SNP) | VAF 38/81 reads (47%) | catalogued as rs761741368; called by muse, mutect2, varscan2
- KCNV2 | c.843C>T p.T281= | Silent (SNP) | VAF 78/188 reads (41%) | catalogued as rs1448724897; called by muse, mutect2, varscan2
- KIAA1549 | c.2046G>A p.Q682= | Silent (SNP) | VAF 66/179 reads (37%) | catalogued as COSV99649854; called by muse, mutect2, varscan2
- LAG3 | c.1530G>A p.P510= | Silent (SNP) | VAF 82/179 reads (46%) | catalogued as rs778100099; called by muse, mutect2, varscan2
- LINGO3 | c.1068C>T p.C356= | Silent (SNP) | VAF 56/149 reads (38%) | catalogued as COSV68261816; called by muse, mutect2, varscan2
- LMF1 | c.405C>T p.G135= | Silent (SNP) | VAF 129/316 reads (41%) | called by muse, mutect2, varscan2
- MAGI2 | c.1089C>T p.G363= | Silent (SNP) | VAF 44/106 reads (42%) | called by muse, mutect2, varscan2
- MASP2 | c.1909C>T p.L637= | Silent (SNP) | VAF 15/45 reads (33%) | catalogued as rs752089778; called by muse, mutect2, varscan2
- MED12L | c.2475T>C p.P825= | Silent (SNP) | VAF 63/142 reads (44%) | called by muse, mutect2, varscan2
- MERTK | c.543T>C p.N181= | Silent (SNP) | VAF 152/339 reads (45%) | called by muse, mutect2, varscan2
- MEST | c.744T>C p.I248= | Silent (SNP) | VAF 36/92 reads (39%) | catalogued as COSV56227645; called by muse, mutect2, varscan2
- MYBPHL | c.378C>T p.R126= | Silent (SNP) | VAF 32/96 reads (33%) | catalogued as rs184070838; called by muse, mutect2, varscan2
- NHS | c.3723G>A p.T1241= | Silent (SNP) | VAF 90/203 reads (44%) | catalogued as rs150235442; ClinVar: likely benign; called by muse, mutect2, varscan2
- NKX2-6 | c.522G>A p.T174= | Silent (SNP) | VAF 103/318 reads (32%) | catalogued as COSV61492934; called by muse, mutect2, varscan2
- NUMA1 | c.1191G>A p.L397= | Silent (SNP) | VAF 67/179 reads (37%) | called by muse, mutect2, varscan2
- NUP160 | c.3432G>A p.Q1144= | Silent (SNP) | VAF 40/69 reads (58%) | called by muse, mutect2, varscan2
- OAF | c.468C>T p.P156= | Silent (SNP) | VAF 24/63 reads (38%) | called by muse, mutect2, varscan2
- OR52D1 | c.201C>T p.C67= | Silent (SNP) | VAF 65/172 reads (38%) | called by muse, mutect2, varscan2
- PACS2 | c.1086C>T p.G362= | Silent (SNP) | VAF 8/140 reads (6%) | called by muse, mutect2
- PASK | c.1233C>T p.V411= | Silent (SNP) | VAF 100/237 reads (42%) | catalogued as rs775075262; called by muse, mutect2, varscan2
- PCDH11X | c.2970C>T p.S990= | Silent (SNP) | VAF 174/428 reads (41%) | catalogued as COSV53458701; called by muse, mutect2, varscan2
- PCDH17 | c.1914C>T p.I638= | Silent (SNP) | VAF 58/135 reads (43%) | catalogued as rs780891643, COSV64973629, COSV64975900; called by muse, mutect2, varscan2
- PCDHGA10 | c.273G>A p.A91= | Silent (SNP) | VAF 62/167 reads (37%) | catalogued as rs781717265; called by muse, varscan2
- PDE4D | c.183G>A p.P61= | Silent (SNP) | VAF 72/160 reads (45%) | called by muse, varscan2
- PDIA5 | c.738G>A p.G246= | Silent (SNP) | VAF 76/171 reads (44%) | catalogued as rs777724538, COSV60247221; called by muse, mutect2, varscan2
- PDZD8 | c.1164T>C p.D388= | Silent (SNP) | VAF 71/156 reads (46%) | called by muse, mutect2, varscan2
- PLEKHG1 | c.3519T>C p.A1173= | Silent (SNP) | VAF 131/291 reads (45%) | called by muse, mutect2, varscan2
- PLXNA2 | c.45C>T p.S15= | Silent (SNP) | VAF 51/121 reads (42%) | catalogued as rs992320345; called by muse, mutect2, varscan2
- PML | c.2446C>A p.R816= | Silent (SNP) | VAF 68/183 reads (37%) | called by muse, mutect2, varscan2
- PNISR | c.1098G>A p.T366= | Silent (SNP) | VAF 90/264 reads (34%) | catalogued as rs148846721; called by muse, mutect2, varscan2
- PPP1R13L | c.144G>A p.S48= | Silent (SNP) | VAF 36/97 reads (37%) | catalogued as rs190656904; called by muse, mutect2, varscan2
- PPP1R16A | c.1278G>A p.K426= | Silent (SNP) | VAF 39/82 reads (48%) | called by muse, mutect2, varscan2
- PRDM16 | c.993C>T p.H331= | Silent (SNP) | VAF 50/149 reads (34%) | catalogued as rs374504712; called by muse, mutect2, varscan2
- PRM3 | c.33C>T p.G11= | Silent (SNP) | VAF 27/52 reads (52%) | catalogued as rs768697922; called by muse, mutect2, varscan2
- PROB1 | c.81C>A p.S27= | Silent (SNP) | VAF 22/42 reads (52%) | called by muse, mutect2, varscan2
- PRRC2A | c.234A>G p.L78= | Silent (SNP) | VAF 54/149 reads (36%) | called by muse, mutect2, varscan2
- PRSS54 | c.210C>T p.G70= | Silent (SNP) | VAF 61/189 reads (32%) | called by muse, mutect2, varscan2
- PTGES3L-AARSD1 | c.846A>G p.V282= (on ENST00000421990 / NM_001136042.2; = p.V264= on NM_025267.3) | Silent (SNP) | VAF 53/119 reads (45%) | called by muse, mutect2, varscan2
- PTH2R | c.1362C>A p.T454= | Silent (SNP) | VAF 31/65 reads (48%) | called by muse, mutect2, varscan2
- PYGO2 | c.1110C>T p.T370= | Silent (SNP) | VAF 66/213 reads (31%) | called by muse, mutect2, varscan2
- RACK1 | c.909G>A p.T303= | Silent (SNP) | VAF 40/82 reads (49%) | catalogued as rs149248823; called by muse, varscan2
- RBMXL2 | c.549C>A p.A183= | Silent (SNP) | VAF 18/34 reads (53%) | catalogued as COSV60979189; called by muse, mutect2
- SAMD4A | c.1998G>A p.L666= | Silent (SNP) | VAF 32/74 reads (43%) | called by muse, mutect2, varscan2
- SCGB1C1 | c.237G>A p.A79= | Silent (SNP) | VAF 74/170 reads (44%) | catalogued as rs201449449, COSV57292777; called by muse, mutect2, varscan2
- SETD6 | c.666C>A p.A222= (on ENST00000219315 / NM_001160305.4; = p.A198= on NM_024860.3) | Silent (SNP) | VAF 42/94 reads (45%) | catalogued as COSV99262020; called by muse, mutect2, varscan2
- SGSM2 | c.684G>A p.R228= | Silent (SNP) | VAF 68/148 reads (46%) | called by muse, mutect2, varscan2
- SHANK2 | c.588C>T p.T196= | Silent (SNP) | VAF 122/278 reads (44%) | catalogued as rs1267512792; called by muse, mutect2, varscan2
- SLC12A4 | c.1056C>A p.S352= | Silent (SNP) | VAF 83/258 reads (32%) | catalogued as COSV57935446; called by muse, mutect2, varscan2
- SLC12A8 | c.91C>T p.L31= | Silent (SNP) | VAF 47/99 reads (47%) | called by muse, mutect2, varscan2
- SLC29A4 | c.498C>T p.Y166= | Silent (SNP) | VAF 17/87 reads (20%) | catalogued as rs373158173; called by muse, mutect2, varscan2
- SLC35A4 | c.828C>T p.S276= | Silent (SNP) | VAF 56/107 reads (52%) | called by muse, mutect2, varscan2
- SLIT1 | c.3168C>T p.H1056= | Silent (SNP) | VAF 64/172 reads (37%) | catalogued as rs141110554; called by muse, mutect2, varscan2
- SMIM12 | c.66C>T p.F22= | Silent (SNP) | VAF 51/111 reads (46%) | catalogued as rs768384287; called by muse, mutect2, varscan2
- SNRNP200 | c.3354C>T p.I1118= | Silent (SNP) | VAF 121/349 reads (35%) | catalogued as rs376352502; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SOWAHA | c.360G>A p.P120= | Silent (SNP) | VAF 58/187 reads (31%) | catalogued as rs1450977057; called by muse, mutect2, varscan2
- SPPL2C | c.84C>T p.H28= | Silent (SNP) | VAF 74/146 reads (51%) | catalogued as rs752646259; called by muse, mutect2, varscan2
- SPTAN1 | c.267A>G p.E89= | Silent (SNP) | VAF 100/409 reads (24%) | called by muse, mutect2, varscan2
- SSC5D | c.4188C>A p.S1396= | Silent (SNP) | VAF 75/224 reads (33%) | called by muse, mutect2, varscan2
- SYCP2 | c.4455C>T p.S1485= | Silent (SNP) | VAF 38/110 reads (35%) | catalogued as rs199996042; called by muse, mutect2, varscan2
- TBC1D9B | c.2031C>T p.S677= | Silent (SNP) | VAF 154/353 reads (44%) | catalogued as rs376754900; called by muse, mutect2, varscan2
- TBL3 | c.426C>T p.Y142= | Silent (SNP) | VAF 71/168 reads (42%) | catalogued as rs754673168, COSV60343000; called by muse, mutect2, varscan2
- TMEM131L | c.3993C>T p.S1331= | Silent (SNP) | VAF 39/85 reads (46%) | catalogued as rs147267955; called by muse, mutect2, varscan2
- TMEM260 | c.1293T>G p.P431= | Silent (SNP) | VAF 14/145 reads (10%) | called by muse, mutect2
- TNR | c.3628C>T p.L1210= | Silent (SNP) | VAF 43/111 reads (39%) | catalogued as rs1372624277; called by muse, mutect2, varscan2
- TPGS1 | c.613C>T p.L205= | Silent (SNP) | VAF 41/95 reads (43%) | called by muse, mutect2, varscan2
- TRIO | c.5553G>A p.G1851= | Silent (SNP) | VAF 64/173 reads (37%) | called by muse, mutect2, varscan2
- TRMT61A | c.630C>T p.I210= | Silent (SNP) | VAF 20/41 reads (49%) | catalogued as rs376237424; called by muse, varscan2
- TRRAP | c.9141C>T p.I3047= (on ENST00000359863 / NM_001244580.1; = p.I3018= on NM_003496.3) | Silent (SNP) | VAF 56/143 reads (39%) | catalogued as rs944320481, COSV62847037; called by muse, mutect2, varscan2
- TSBP1 | c.1419A>G p.S473= (on ENST00000617061; = p.S478= on NM_006781.5) | Silent (SNP) | VAF 119/276 reads (43%) | called by muse, mutect2, varscan2
- TSHZ2 | c.90G>A p.E30= | Silent (SNP) | VAF 33/72 reads (46%) | catalogued as COSV61588654; called by muse, mutect2
- TSPO | c.477T>C p.H159= | Silent (SNP) | VAF 69/196 reads (35%) | called by muse, mutect2, varscan2
- UHRF1 | c.2121C>T p.S707= (on ENST00000612630 / NM_001290050.1; = p.S720= on NM_013282.4) | Silent (SNP) | VAF 33/80 reads (41%) | catalogued as rs757548105; called by muse, mutect2, varscan2
- USP7 | c.1458A>G p.S486= | Silent (SNP) | VAF 40/118 reads (34%) | called by muse, mutect2, varscan2
- UTP14C | c.1047A>C p.T349= | Silent (SNP) | VAF 20/288 reads (7%) | called by muse, mutect2
- WDR44 | c.2370C>A p.I790= | Silent (SNP) | VAF 53/136 reads (39%) | called by mutect2, varscan2
- WDR91 | c.792G>A p.S264= | Silent (SNP) | VAF 67/164 reads (41%) | catalogued as rs369872179, COSV100615832; called by muse, mutect2, varscan2
- XDH | c.1794T>G p.P598= | Silent (SNP) | VAF 165/358 reads (46%) | called by muse, mutect2, varscan2
- ZNF521 | c.717C>T p.D239= | Silent (SNP) | VAF 81/186 reads (44%) | called by muse, mutect2, varscan2
- ZNF597 | c.918G>A p.R306= | Silent (SNP) | VAF 69/171 reads (40%) | catalogued as rs150503963; called by muse, mutect2, varscan2
- ZNF648 | c.1101C>T p.S367= | Silent (SNP) | VAF 82/188 reads (44%) | catalogued as rs752457526; called by muse, mutect2, varscan2
- ABCC6P1 | n.485del | RNA (DEL) | VAF 67/273 reads (25%) | called by mutect2, pindel, varscan2
- AC022364.1 | chr12:28183733 del T | 3'Flank (DEL) | VAF 29/158 reads (18%) | called by mutect2, pindel, varscan2
- AC055839.2 | chr17:5501879 T>C | 5'Flank (SNP) | VAF 79/180 reads (44%) | called by muse, mutect2, varscan2
- AC104389.6 | c.-4C>T | 5'UTR (SNP) | VAF 44/250 reads (18%) | catalogued as rs1369525682; called by muse, mutect2
- AC125421.1 | n.325-206T>C | Intron (SNP) | VAF 104/226 reads (46%) | called by muse, mutect2, varscan2
- ADAM7 | c.2209-1360G>A | Intron (SNP) | VAF 52/144 reads (36%) | catalogued as rs1258866319; called by muse, mutect2, varscan2
- AKAP8L | c.-41A>T | 5'UTR (SNP) | VAF 20/55 reads (36%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73850722 del G | 3'Flank (DEL) | VAF 10/26 reads (38%) | called by mutect2, pindel
- AP1M2 | c.42+14T>C | Intron (SNP) | VAF 47/111 reads (42%) | called by muse, mutect2, varscan2
- ARHGEF4 | chr2:130914076 T>C | 5'Flank (SNP) | VAF 135/358 reads (38%) | catalogued as rs149365221; called by muse, mutect2, varscan2
- C2 | c.849+26G>A | Intron (SNP) | VAF 88/234 reads (38%) | called by muse, mutect2, varscan2
- CAPN1 | chr11:65181614 del C | 5'Flank (DEL) | VAF 19/86 reads (22%) | called by mutect2, pindel, varscan2
- CAPN8 | c.899+12del | Intron (DEL) | VAF 47/136 reads (35%) | catalogued as rs746529632; called by mutect2, pindel, varscan2
- CCDC74B | c.296-286C>T | Intron (SNP) | VAF 149/355 reads (42%) | called by muse, mutect2, varscan2
- CLRN1 | c.*676del | 3'UTR (DEL) | VAF 75/191 reads (39%) | called by mutect2, pindel, varscan2
- COL20A1 | c.3295-11del | Intron (DEL) | VAF 46/139 reads (33%) | catalogued as rs1284398323; called by mutect2, pindel, varscan2
- CUL4A | chr13:113208557 A>G | 5'Flank (SNP) | VAF 97/232 reads (42%) | called by muse, mutect2, varscan2
- CYB5A | c.289-1094del | Intron (DEL) | VAF 63/162 reads (39%) | called by mutect2, varscan2
- CYP21A2 | c.652-25T>C | Intron (SNP) | VAF 136/346 reads (39%) | called by muse, mutect2, varscan2
- CYP4V2 | c.988-26del | Intron (DEL) | VAF 63/225 reads (28%) | called by mutect2, pindel, varscan2
- DMTN | c.*405G>A | 3'UTR (SNP) | VAF 47/116 reads (41%) | called by muse, mutect2, varscan2
- DNM2 | c.*13del | 3'UTR (DEL) | VAF 20/78 reads (26%) | catalogued as rs758093165; called by mutect2, pindel, varscan2
- DOCK9 | c.2043+14del | Intron (DEL) | VAF 36/87 reads (41%) | catalogued as rs747598066; called by mutect2, varscan2
- DYNC1H1 | c.5050-26A>G | Intron (SNP) | VAF 108/292 reads (37%) | catalogued as rs1303087716; called by muse, mutect2, varscan2
- ELAVL4 | c.-33C>T | 5'UTR (SNP) | VAF 16/33 reads (48%) | catalogued as rs1179374538; called by muse, mutect2, varscan2
- FAM20A | c.*1807_*1808del | 3'UTR (DEL) | VAF 14/107 reads (13%) | called by pindel, varscan2
- FOXL2NB | c.220+51C>A | Intron (SNP) | VAF 34/103 reads (33%) | called by muse, mutect2, varscan2
- GCH1 | c.*17-63del | Intron (DEL) | VAF 20/67 reads (30%) | catalogued as rs918838734; called by mutect2, varscan2
- GFRA1 | c.*14del | 3'UTR (DEL) | VAF 71/200 reads (36%) | called by mutect2, pindel, varscan2
- GINM1 | c.-14C>T | 5'UTR (SNP) | VAF 31/65 reads (48%) | catalogued as rs1406676834; called by muse, mutect2, varscan2
- GLIS2 | c.*32del | 3'UTR (DEL) | VAF 77/240 reads (32%) | catalogued as rs551297578; called by mutect2, pindel, varscan2
- GPR132 | c.-760G>A | 5'UTR (SNP) | VAF 65/147 reads (44%) | catalogued as rs558628732; called by muse, mutect2, varscan2
- HACE1 | c.1075-64_1075-61del | Intron (DEL) | VAF 12/46 reads (26%) | catalogued as rs1477178457; called by pindel, varscan2
- HMCN1 | c.-13del | 5'UTR (DEL) | VAF 41/136 reads (30%) | called by mutect2, varscan2
- IQCE | c.394+407G>A | Intron (SNP) | VAF 52/157 reads (33%) | catalogued as rs761117394; called by muse, varscan2
- IRF1-AS1 | n.162G>A | RNA (SNP) | VAF 49/156 reads (31%) | called by muse, mutect2, varscan2
- ITSN2 | c.654-145G>A | Intron (SNP) | VAF 37/101 reads (37%) | catalogued as rs761687029; called by muse, mutect2, varscan2
- KIFC3 | c.315+9420T>C | Intron (SNP) | VAF 37/84 reads (44%) | called by muse, mutect2, varscan2
- KLHL2 | c.152+3926G>A | Intron (SNP) | VAF 18/62 reads (29%) | called by muse, mutect2, varscan2
- KRT8 | c.*66C>T | 3'UTR (SNP) | VAF 55/140 reads (39%) | called by muse, mutect2, varscan2
- L34079.1 | c.169+14134dup | Intron (INS) | VAF 32/118 reads (27%) | called by mutect2, pindel, varscan2
- LINC02076 | n.988G>A | RNA (SNP) | VAF 6/16 reads (38%) | called by mutect2, varscan2
- LRRC9 | c.4131+709del | Intron (DEL) | VAF 43/132 reads (33%) | catalogued as rs1231009409; called by mutect2, pindel, varscan2
- MAGOHB | c.264+463T>C | Intron (SNP) | VAF 28/60 reads (47%) | called by muse, mutect2, varscan2
- MAP3K7CL | c.370+16590G>C | Intron (SNP) | VAF 78/196 reads (40%) | called by muse, mutect2, varscan2
- MAPK8IP1P2 | n.332G>A | RNA (SNP) | VAF 41/179 reads (23%) | called by muse, mutect2, varscan2
- MECP2 | c.-41G>T | 5'UTR (SNP) | VAF 12/356 reads (3%) | called by muse, mutect2
- MED23 | c.*38G>A | 3'UTR (SNP) | VAF 82/201 reads (41%) | catalogued as rs754340396; called by muse, mutect2, varscan2
- MIR1303 | n.46_48del | RNA (DEL) | VAF 26/86 reads (30%) | catalogued as rs747084698; called by pindel, varscan2
- MIR4739 | chr17:79707388 C>T | 5'Flank (SNP) | VAF 39/232 reads (17%) | called by muse, mutect2, varscan2
- MPV17 | c.71-39C>A | Intron (SNP) | VAF 76/213 reads (36%) | called by muse, mutect2, varscan2
- MTHFR | c.-13-390_-13-389del | Intron (DEL) | VAF 38/106 reads (36%) | called by mutect2, pindel, varscan2
- NABP1 | c.302+53C>T | Intron (SNP) | VAF 6/18 reads (33%) | catalogued as rs530687018; called by muse, mutect2, varscan2
- NACA | c.71-3003C>T | Intron (SNP) | VAF 6/10 reads (60%) | called by muse, mutect2, varscan2
- NCF1 | c.153+35C>T | Intron (SNP) | VAF 40/117 reads (34%) | catalogued as rs1554413159; called by muse, mutect2, varscan2
- NEK8 | c.827+16G>A | Intron (SNP) | VAF 82/155 reads (53%) | called by muse, mutect2, varscan2
- NOP14 | c.*20-43del | Intron (DEL) | VAF 34/91 reads (37%) | catalogued as rs780378788; called by mutect2, varscan2
- NOS1AP | c.*25C>T | 3'UTR (SNP) | VAF 10/24 reads (42%) | catalogued as rs769423337; called by muse, mutect2, varscan2
- NPC1L1 | c.-21T>C | 5'UTR (SNP) | VAF 33/77 reads (43%) | catalogued as rs1257403648; called by muse, mutect2, varscan2
- NPIPB4 | c.121-4458C>T | Intron (SNP) | VAF 75/528 reads (14%) | catalogued as rs751185673; called by muse, mutect2, varscan2
- NR1I3 | c.823+76C>T | Intron (SNP) | VAF 52/135 reads (39%) | called by muse, mutect2, varscan2
- OLFM1 | c.-23C>T | 5'UTR (SNP) | VAF 29/62 reads (47%) | catalogued as rs1486582683; called by muse, mutect2, varscan2
- OR5E1P | n.415C>T | RNA (SNP) | VAF 41/86 reads (48%) | called by muse, mutect2, varscan2
- PAX8 | c.777+89G>A | Intron (SNP) | VAF 45/130 reads (35%) | called by muse, mutect2, varscan2
- PDE4DIP | c.441+1659del | Intron (DEL) | VAF 9/34 reads (26%) | catalogued as rs782012470; called by mutect2, pindel, varscan2
- PDSS2 | c.630+9606A>G | Intron (SNP) | VAF 61/140 reads (44%) | called by muse, mutect2, varscan2
- PEG10 | c.*1100G>T | 3'UTR (SNP) | VAF 52/116 reads (45%) | called by muse, mutect2
- PHOX2B | c.*31C>T | 3'UTR (SNP) | VAF 59/126 reads (47%) | catalogued as COSV56930230; called by mutect2, varscan2
- PLA2G6 | c.1077+715del | Intron (DEL) | VAF 36/95 reads (38%) | catalogued as rs998817264; called by mutect2, varscan2
- POC1B-GALNT4 | c.-117C>T | 5'UTR (SNP) | VAF 36/106 reads (34%) | called by muse, mutect2, varscan2
- PRR12 | chr19:49595100 C>T | 5'Flank (SNP) | VAF 115/296 reads (39%) | catalogued as rs748529964; called by muse, mutect2, varscan2
- PSD3 | c.2086+32T>C | Intron (SNP) | VAF 56/146 reads (38%) | called by muse, mutect2, varscan2
- QKI | c.935-53del | Intron (DEL) | VAF 67/164 reads (41%) | catalogued as rs372217972; called by mutect2, pindel, varscan2
- RAB18 | c.*178A>C | 3'UTR (SNP) | VAF 125/290 reads (43%) | called by muse, mutect2, varscan2
- RAB3GAP1 | c.150+60G>A | Intron (SNP) | VAF 97/203 reads (48%) | called by muse, mutect2, varscan2
- RBM44 | c.-98-2821dup | Intron (INS) | VAF 18/50 reads (36%) | catalogued as rs746070623; called by mutect2, varscan2
- RERE | c.1203+127G>A | Intron (SNP) | VAF 73/184 reads (40%) | catalogued as rs750497688; called by muse, mutect2, varscan2
- SET | c.113-5dup | Intron (INS) | VAF 40/141 reads (28%) | catalogued as rs773080956; called by pindel, varscan2
- SGK1 | c.285+98del | Intron (DEL) | VAF 24/64 reads (38%) | catalogued as rs1204601577, COSV63116269; called by mutect2, pindel, varscan2
- SH3KBP1 | c.521-3657C>T | Intron (SNP) | VAF 12/182 reads (7%) | called by muse, mutect2
- SLC12A6 | c.-19del | 5'UTR (DEL) | VAF 16/199 reads (8%) | catalogued as rs1566881500; called by mutect2, pindel
- SLC25A21 | c.*19del | 3'UTR (DEL) | VAF 36/110 reads (33%) | called by mutect2, pindel, varscan2
- SLC41A3 | c.274-5333C>T | Intron (SNP) | VAF 47/109 reads (43%) | catalogued as COSV59986989; called by muse, mutect2, varscan2
- SPCS2P4 | n.599G>A | RNA (SNP) | VAF 70/189 reads (37%) | catalogued as rs746847915; called by muse, varscan2
- SREBF2 | c.2907+466A>G | Intron (SNP) | VAF 74/167 reads (44%) | called by muse, mutect2, varscan2
- SRRM1 | c.1629-35del | Intron (DEL) | VAF 40/83 reads (48%) | catalogued as rs761064971; called by mutect2, varscan2
- STIM1 | c.1541+101G>A | Intron (SNP) | VAF 103/268 reads (38%) | catalogued as rs548943505; called by muse, varscan2
- SYTL2 | c.1459+794T>G | Intron (SNP) | VAF 45/120 reads (38%) | called by muse, mutect2, varscan2
- TAMM41 | c.136-762C>T | Intron (SNP) | VAF 70/179 reads (39%) | catalogued as rs552187890; called by muse, mutect2, varscan2
- TECR | c.15+21del | Intron (DEL) | VAF 81/235 reads (34%) | called by mutect2, pindel, varscan2
- TIMM17B | c.127-274A>G | Intron (SNP) | VAF 41/103 reads (40%) | called by muse, mutect2, varscan2
- TMEM183B | n.175G>A | RNA (SNP) | VAF 72/202 reads (36%) | catalogued as rs772979194; called by muse, mutect2, varscan2
- TMPRSS11BNL | n.331T>C | RNA (SNP) | VAF 25/64 reads (39%) | called by muse, mutect2, varscan2
- TMPRSS11F | c.1015+1579G>A | Intron (SNP) | VAF 51/127 reads (40%) | catalogued as rs776527982; called by muse, mutect2, varscan2
- TNFRSF10B | c.748+51T>C | Intron (SNP) | VAF 58/152 reads (38%) | called by mutect2, varscan2
- TRAPPC12 | c.1776+636C>T | Intron (SNP) | VAF 51/147 reads (35%) | called by muse, mutect2, varscan2
- UAP1L1 | c.495-72G>A | Intron (SNP) | VAF 26/81 reads (32%) | called by muse, mutect2
- UBE2I | c.413+113C>T | Intron (SNP) | VAF 42/86 reads (49%) | catalogued as rs777918561; called by muse, mutect2
- UBQLN2 | c.-4C>T | 5'UTR (SNP) | VAF 10/28 reads (36%) | catalogued as rs755736386; called by muse, mutect2
- VAMP1 | c.289-371_289-370del | Intron (DEL) | VAF 34/121 reads (28%) | called by pindel, varscan2
- ZNF638 | c.2378-2565T>C | Intron (SNP) | VAF 67/173 reads (39%) | called by muse, mutect2, varscan2
